Somatic mutation profile of tumor specimen TCGA-HU-A4GX-01A (aliquot TCGA-HU-A4GX-01A-12D-A25D-08) from TCGA case TCGA-HU-A4GX, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 70.9 years (25,913 days).
Specimen TCGA-HU-A4GX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 061b73a0-4a72-4038-9108-6ac4d55b5f0c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HU-A4GX-10A (Blood Derived Normal), aliquot TCGA-HU-A4GX-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b4106c77-a4f0-4cfc-8bd0-f3b76963136a

The open-access MAF lists 1,479 somatic variants for this specimen: 1,143 protein-altering or splice-affecting, 311 silent, 25 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 722, Silent 311, Frame Shift Del 276, Nonsense Mutation 46, Frame Shift Ins 43, Splice Site 24, In Frame Del 20, Splice Region 11, 3'UTR 9, Intron 7, RNA 6, 3'Flank 2.

Variants (750 of 1,479; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHST3 | c.533del p.G178Afs*38 | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | catalogued as rs769540174; ClinVar: likely pathogenic / pathogenic; called by pindel, varscan2
- LARP7 | c.1213del p.T405Qfs*5 | Frame Shift Del (DEL) | VAF 6/14 reads (43%) | catalogued as rs750946801; ClinVar: likely pathogenic; called by mutect2, varscan2
- LTBP3 | c.2216dup p.G740Rfs*51 | Frame Shift Ins (INS) | VAF 17/63 reads (27%) | catalogued as rs752375653; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MEN1 | c.1561del p.R521Gfs*43 | Frame Shift Del (DEL) | VAF 5/25 reads (20%) | catalogued as rs767319284, CD972318, CM080439, COSV53644931; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 22/112 reads (20%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- MTHFR | c.1072C>T p.R358* | Nonsense Mutation (SNP) | VAF 49/121 reads (40%) | catalogued as rs377443637, CM983383; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NIPBL | c.1808del p.K603Sfs*11 | Frame Shift Del (DEL) | VAF 14/50 reads (28%) | catalogued as rs727503767; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 13/64 reads (20%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SACS | c.3328del p.I1110Lfs*16 | Frame Shift Del (DEL) | VAF 38/192 reads (20%) | catalogued as rs770866403; ClinVar: likely pathogenic; called by mutect2, varscan2
- SPG11 | c.3075del p.E1026Sfs*12 | Frame Shift Del (DEL) | VAF 7/33 reads (21%) | catalogued as rs312262752; ClinVar: pathogenic; called by mutect2, varscan2
- AARS2 | c.935C>T p.A312V | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.109); catalogued as COSV99771441; called by muse, mutect2
- ABCB4 | c.3269C>T p.A1090V | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.273); catalogued as rs143392573; called by muse, mutect2, varscan2
- ABCB5 | c.3101G>A p.R1034H (on ENST00000404938 / NM_001163941.2; = p.R589H on NM_178559.6) | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs960822608, COSV51702454; called by muse, mutect2, varscan2
- ABCC1 | c.1442C>A p.A481D | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60679279; called by muse, mutect2, varscan2
- ABCC5 | c.3269del p.L1090Cfs*26 | Frame Shift Del (DEL) | VAF 12/40 reads (30%) | catalogued as rs749943218; called by mutect2, varscan2
- ABCC9 | c.1993G>A p.A665T | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs200891785, CM141607, COSV53961570; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCF3 | c.481A>G p.S161G | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.114); catalogued as rs1280268862, COSV53046857; called by muse, mutect2, varscan2
- ABLIM1 | c.95C>T p.S32L | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs747877624, COSV53298908; called by muse, mutect2, varscan2
- ABLIM2 | c.944C>T p.A315V | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56399534; called by muse, mutect2, varscan2
- ABLIM3 | c.151G>T p.V51L | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.81); catalogued as COSV58638794; called by muse, mutect2, varscan2
- ABR | c.1328C>T p.S443L (on ENST00000302538 / NM_021962.5; = p.S406L on NM_001092.5) | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.577); catalogued as COSV52140988; called by muse, mutect2, varscan2
- ACAP1 | c.1186G>A p.A396T | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV50134011; called by muse, mutect2, varscan2
- ACLY | c.443A>C p.K148T | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV61249081; called by muse, mutect2, varscan2
- ACSM1 | c.965G>A p.R322Q | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs146842441, COSV54632756, COSV54637011; called by muse, mutect2, varscan2
- ACSS2 | c.806del p.P269Qfs*69 | Frame Shift Del (DEL) | VAF 11/45 reads (24%) | catalogued as rs745681981, COSV53623223; called by mutect2, pindel, varscan2
- ACTN3 | c.898C>T p.L300= | Splice Region (SNP) | VAF 5/28 reads (18%) | catalogued as rs1161094835, COSV72207522; called by muse, mutect2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 33/68 reads (49%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM32 | c.622A>T p.I208L | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV65946842; called by muse, mutect2, varscan2
- ADAMTS9 | c.637del p.Q213Rfs*42 | Frame Shift Del (DEL) | VAF 6/33 reads (18%) | catalogued as rs1559825709, COSV55789887; called by mutect2, pindel, varscan2
- ADCK1 | c.1277G>A p.R426H | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs112630340, COSV53078037; called by muse, mutect2, varscan2
- ADCY6 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 60/147 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV57166022; called by muse, mutect2, varscan2
- ADCY8 | c.2686G>T p.G896W | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.914); catalogued as COSV53894891; called by muse, mutect2, varscan2
- ADD2 | c.1973C>T p.A658V | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV100035611; called by muse, mutect2, varscan2
- ADD2 | c.1423A>G p.M475V | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV52454037; called by muse, mutect2, varscan2
- ADD2 | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs372010773; called by muse, mutect2, varscan2
- ADGRL1 | c.2219C>T p.T740M (on ENST00000340736 / NM_001008701.3; = p.T735M on NM_014921.5) | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1317471210, COSV61563464; called by muse, mutect2, varscan2
- ADRA2B | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as rs753262027, COSV69787112; called by muse, mutect2, varscan2
- AFF2 | c.3413T>C p.M1138T | Missense Mutation (SNP) | VAF 37/168 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV53974665; called by muse, mutect2, varscan2
- AFMID | c.820C>T p.L274F | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); catalogued as COSV59975320; called by muse, mutect2, varscan2
- AGBL2 | c.2635A>G p.R879G | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.248); catalogued as COSV54089764; called by muse, mutect2, varscan2
- AGO2 | c.1806del p.A603Pfs*92 | Frame Shift Del (DEL) | VAF 49/243 reads (20%) | catalogued as rs748399150; called by mutect2, pindel, varscan2
- AGXT2 | c.1445G>A p.R482H | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746146731, COSV51483571; called by muse, mutect2, varscan2
- AHCYL2 | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as rs1175608941, COSV61484835; called by muse, mutect2, varscan2
- AHI1 | c.3380G>T p.S1127I | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV55622278; called by muse, mutect2
- AJM1 | c.1180C>T p.H394Y | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99915639; called by muse, mutect2
- AKAP11 | c.4195C>T p.P1399S | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.058); catalogued as rs1230045522, COSV50292439; called by muse, mutect2, varscan2
- AKAP12 | c.4757A>G p.D1586G | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as COSV53569752; called by muse, mutect2, varscan2
- AKR1C1 | c.682G>A p.V228M | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.528); catalogued as COSV66498424; called by muse, mutect2, varscan2
- AKT2 | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.098); catalogued as COSV60907432; called by muse, mutect2, varscan2
- ALB | c.863T>A p.I288N | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV55735427, COSV99891536; called by muse, mutect2, varscan2
- ALDH8A1 | c.1204T>C p.F402L | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55639823; called by muse, mutect2, varscan2
- ALDOB | c.521A>G p.Y174C | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66397214; called by muse, mutect2, varscan2
- ALK | c.4435G>A p.A1479T | Missense Mutation (SNP) | VAF 44/160 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.476); catalogued as COSV66555657; called by muse, mutect2, varscan2
- ALOX12 | c.1684C>T p.R562W | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); catalogued as rs768496365, COSV52348362; called by muse, mutect2, varscan2
- ALPK1 | c.901-2A>G p.X301_splice | Splice Site (SNP) | VAF 7/43 reads (16%) | catalogued as COSV51581240; called by muse, mutect2, varscan2
- ALPK2 | c.6196C>T p.H2066Y | Missense Mutation (SNP) | VAF 49/169 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64489832; called by muse, mutect2, varscan2
- ANAPC7 | c.1069C>T p.R357W | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71443661; called by muse, mutect2, varscan2
- ANGPT2 | c.700del p.I234* | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | catalogued as rs34047276; called by mutect2, varscan2
- ANGPTL5 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as rs369448584, COSV57531632; called by muse, mutect2
- ANK3 | c.76del p.R26Gfs*21 | Frame Shift Del (DEL) | VAF 23/76 reads (30%) | catalogued as rs1373792937; called by mutect2, pindel, varscan2
- ANKFY1 | c.2072del p.P691Rfs*61 (on ENST00000341657 / NM_001330063.2; = p.P692Rfs*61 on NM_016376.5) | Frame Shift Del (DEL) | VAF 39/174 reads (22%) | catalogued as COSV58920130; called by mutect2, pindel, varscan2
- ANKHD1-EIF4EBP3 | c.2513T>G p.L838R | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV51839595; called by muse, mutect2, varscan2
- ANKRD13B | c.863G>A p.R288Q | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61470044; called by muse, mutect2, varscan2
- ANKRD35 | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.961); catalogued as COSV62909399; called by muse, mutect2, varscan2
- ANOS1 | c.1502C>T p.T501I | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as COSV52915323; called by muse, mutect2, varscan2
- ANXA2 | c.877G>A p.V293I | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.05); catalogued as rs777367502, COSV60315432; called by mutect2, varscan2
- ANXA7 | c.913C>T p.R305* (on ENST00000372919 / NM_001320880.2; = p.R283* on NM_001156.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 6/35 reads (17%) | catalogued as rs763704857, COSV65822784; called by mutect2, varscan2
- AP2B1 | c.1583G>A p.R528H | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV51996641; called by muse, mutect2, varscan2
- AP3M2 | c.505C>T p.R169W | Missense Mutation (SNP) | VAF 56/270 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1313487729, COSV51527429; called by muse, mutect2, varscan2
- AP4M1 | c.254+2T>C p.X85_splice | Splice Site (SNP) | VAF 19/122 reads (16%) | catalogued as COSV57993654; called by muse, mutect2, varscan2
- APC2 | c.3691C>A p.L1231M | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.798); catalogued as COSV52015917, COSV52019210; called by muse, mutect2, varscan2
- APPL1 | c.460del p.R154Efs*6 | Frame Shift Del (DEL) | VAF 11/27 reads (41%) | catalogued as rs749401724; called by mutect2, varscan2
- ARAP3 | c.1620G>T p.K540N | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV53348251; called by muse, mutect2, varscan2
- ARFGAP2 | c.276del p.R93Afs*43 | Frame Shift Del (DEL) | VAF 42/152 reads (28%) | catalogued as rs772728725, COSV54066450; called by mutect2, pindel, varscan2
- ARHGAP45 | c.757G>T p.G253C | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV57428515; called by muse, mutect2
- ARID1A | c.3977dup p.Q1327Afs*11 | Frame Shift Ins (INS) | VAF 30/138 reads (22%) | catalogued as COSV61376881; called by pindel, varscan2
- ARID1B | c.4318C>T p.Q1440* | Nonsense Mutation (SNP) | VAF 12/50 reads (24%) | catalogued as rs1554235684, CM160617, COSV51647037; called by muse, mutect2, varscan2
- ASAP1 | c.3259A>G p.T1087A | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV63043901; called by muse, mutect2, varscan2
- ASAP3 | c.293G>A p.G98D | Missense Mutation (SNP) | VAF 45/145 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60872762; called by muse, mutect2, varscan2
- ASPM | c.5985del p.A1996Lfs*4 | Frame Shift Del (DEL) | VAF 16/75 reads (21%) | catalogued as COSV99659691; called by mutect2, pindel, varscan2
- ATF7IP2 | c.1211C>T p.A404V | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV104410060, COSV61092028; called by muse, mutect2, varscan2
- ATP10D | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.334); catalogued as rs770945581, COSV56703258; called by muse, mutect2, varscan2
- ATP11B | c.2650del p.Y884Ifs*30 | Frame Shift Del (DEL) | VAF 13/32 reads (41%) | catalogued as rs759638000; called by mutect2, varscan2
- ATP13A2 | c.59C>T p.T20M | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as rs773699589, COSV58697749; called by muse, mutect2, varscan2
- ATP1A3 | c.396+1G>A p.X132_splice (on ENST00000545399 / NM_001256214.2; = p.X119_splice on NM_152296.5) | Splice Site (SNP) | VAF 34/126 reads (27%) | catalogued as COSV57484714; called by muse, mutect2, varscan2
- ATP4A | c.1972C>T p.R658C | Missense Mutation (SNP) | VAF 61/208 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.632); catalogued as rs767990060, COSV52865161; called by muse, mutect2, varscan2
- ATP8B1 | c.3614G>A p.R1205Q | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.545); catalogued as COSV52172711; called by muse, mutect2
- ATP8B2 | c.2174C>T p.T725M (on ENST00000672630; = p.T692M on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs367934414; called by muse, mutect2, varscan2
- ATXN2 | c.3289del p.A1097Lfs*109 (on ENST00000550104; = p.A937Lfs*109 on NM_002973.4) | Frame Shift Del (DEL) | VAF 39/121 reads (32%) | catalogued as COSV66482708; called by mutect2, pindel, varscan2
- B4GALT7 | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.105); catalogued as rs764639019, COSV50352584; called by muse, mutect2, varscan2
- BACH2 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.148); catalogued as rs61740507, COSV57582961; called by muse, mutect2, varscan2
- BAHD1 | c.1735C>T p.R579C | Missense Mutation (SNP) | VAF 46/181 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as rs778274368, COSV69083555; called by muse, mutect2, varscan2
- BCL11A | c.1745dup p.L583Pfs*18 (on ENST00000335712 / NM_001365609.1; = p.L617Pfs*18 on NM_018014.4) | Frame Shift Ins (INS) | VAF 9/47 reads (19%) | catalogued as rs1382819519; called by mutect2, pindel, varscan2
- BEX1 | c.42G>A p.M14I | Missense Mutation (SNP) | VAF 80/280 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs1276184822, COSV65579595, COSV65580694; called by muse, mutect2, varscan2
- BICD2 | c.1632C>A p.C544* | Nonsense Mutation (SNP) | VAF 30/146 reads (21%) | catalogued as COSV63547807; called by muse, mutect2, varscan2
- BLOC1S4 | c.631T>C p.C211R | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.053); catalogued as COSV57900774; called by muse, mutect2, varscan2
- BPIFB4 | c.718C>T p.R240W | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as rs752406178, COSV64950589, COSV64950633; called by muse, mutect2, varscan2
- BRD2 | c.1427C>T p.S476L | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.195); catalogued as rs756721721, COSV66372254; called by muse, mutect2, varscan2
- BRSK1 | c.1135dup p.R379Pfs*54 | Frame Shift Ins (INS) | VAF 20/100 reads (20%) | catalogued as rs746043904; called by mutect2, varscan2
- BRWD1 | c.2519C>T p.S840L | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV60892326; called by muse, mutect2, varscan2
- BTBD11 | c.3201del p.Y1068Mfs*86 (on ENST00000280758 / NM_001018072.2; = p.Y605Mfs*86 on NM_001017523.2) | Frame Shift Del (DEL) | VAF 11/101 reads (11%) | catalogued as COSV55041134; called by mutect2, pindel, varscan2
- BTBD2 | c.589G>T p.A197S | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.896); catalogued as COSV55307282, COSV55310689; called by muse, mutect2, varscan2
- BTBD7 | c.976A>G p.T326A | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs781110720, COSV54133137; called by muse, mutect2, varscan2
- BTC | c.139G>T p.G47* | Nonsense Mutation (SNP) | VAF 22/65 reads (34%) | catalogued as COSV67547172, COSV67547831; called by muse, mutect2, varscan2
- BTRC | c.1780dup p.R594Pfs*27 (on ENST00000370187 / NM_033637.4; = p.R558Pfs*27 on NM_003939.5) | Frame Shift Ins (INS) | VAF 21/79 reads (27%) | catalogued as rs774921343; called by mutect2, varscan2
- C10orf90 | c.1160A>G p.E387G | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs772876886, COSV52948745; called by muse, mutect2, varscan2
- C16orf89 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as rs774928212, COSV60121930; called by muse, mutect2, varscan2
- C1QTNF1 | c.455G>A p.R152Q | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.954); catalogued as rs1249970744, COSV59260267; called by muse, mutect2, varscan2
- C1orf43 | c.341-2A>C p.X114_splice (on ENST00000368521 / NM_001297718.2; = p.X80_splice on NM_015449.4) | Splice Site (SNP) | VAF 9/52 reads (17%) | catalogued as COSV62965752; called by muse, mutect2, varscan2
- C2CD3 | c.5402C>T p.T1801M | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs370540388; called by muse, mutect2, varscan2
- C2CD3 | c.4706A>G p.H1569R | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs1489690266, COSV58089004; called by muse, mutect2, varscan2
- C2orf16 | c.4357C>T p.R1453* | Nonsense Mutation (SNP) | VAF 48/181 reads (27%) | catalogued as rs557771429, COSV62673324; called by muse, mutect2, varscan2
- C3orf56 | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs766049805, COSV101228953, COSV101228955; called by muse, varscan2
- C6orf118 | c.773C>T p.T258M | Missense Mutation (SNP) | VAF 58/216 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.911); catalogued as rs763430282, COSV57812137; called by muse, mutect2, varscan2
- C7orf65 | n.105G>A | Splice Region (SNP) | VAF 11/60 reads (18%) | catalogued as rs1348685127; called by muse, mutect2, varscan2
- CA2 | c.440del p.L147* | Frame Shift Del (DEL) | VAF 30/124 reads (24%) | catalogued as rs763603775; called by mutect2, pindel, varscan2
- CACNA1B | c.6553G>A p.G2185S | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.708); catalogued as rs538992240, COSV53111911; called by muse, mutect2, varscan2
- CACNA1C | c.910A>G p.I304V | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated (0.73); PolyPhen benign (0.056); catalogued as COSV59694542; called by muse, mutect2, varscan2
- CACNA1C | c.2113G>A p.G705R | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786205750, COSV100215463, COSV59694566; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1D | c.6271G>A p.A2091T (on ENST00000350061 / NM_001128840.3; = p.A2111T on NM_000720.4) | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV55436121; called by muse, mutect2, varscan2
- CACNA1S | c.1961A>G p.N654S | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as rs1210499108, COSV62935596; called by muse, mutect2, varscan2
- CACNA2D3 | c.1708G>A p.V570M | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as rs764866239, COSV99867873; called by muse, mutect2, varscan2
- CACNG1 | c.583G>A p.G195S | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs761507529, COSV56825965; called by muse, mutect2, varscan2
- CALR | c.610C>T p.P204S | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.279); catalogued as COSV57116640; called by muse, mutect2, varscan2
- CAMK4 | c.1061A>G p.K354R | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as COSV56661063; called by muse, mutect2, varscan2
- CAMSAP1 | c.4728T>G p.S1576R | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56717946; called by muse, mutect2, varscan2
- CAMTA2 | c.358G>A p.V120I | Missense Mutation (SNP) | VAF 40/151 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1172448098, COSV61832651; called by muse, mutect2, varscan2
- CAND2 | c.1233G>T p.K411N (on ENST00000456430 / NM_001162499.2; = p.K318N on NM_012298.3) | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV55986216; called by muse, mutect2, varscan2
- CARD11 | c.1663del p.R555Gfs*45 | Frame Shift Del (DEL) | VAF 59/151 reads (39%) | catalogued as rs762770988, COSV62756627; called by mutect2, varscan2
- CARM1 | c.695C>T p.T232M | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.637); catalogued as rs527617157, COSV58998685; called by muse, mutect2, varscan2
- CASKIN1 | c.1594C>A p.L532I | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.402); catalogued as COSV58869515; called by muse, mutect2, varscan2
- CATSPERE | c.649T>C p.F217L | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.121); catalogued as COSV63675574; called by muse, mutect2, varscan2
- CBLC | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.378); catalogued as rs1032029318, COSV54321135; called by muse, mutect2
- CBLL2 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as COSV60368273; called by muse, mutect2, varscan2
- CBX4 | c.1511C>T p.A504V | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.499); catalogued as rs376832453; called by muse, mutect2, varscan2
- CCDC116 | c.974G>A p.R325H | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.597); catalogued as rs367783734; called by muse, varscan2
- CCDC15 | c.581del p.K194Rfs*29 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | catalogued as rs759789184, COSV99049086; called by mutect2, varscan2
- CCDC171 | c.2590C>A p.L864I | Missense Mutation (SNP) | VAF 50/185 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.104); catalogued as COSV52633189; called by muse, mutect2, varscan2
- CCDC74B | c.39del p.S14Afs*21 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | catalogued as rs1198697781; called by mutect2, varscan2
- CCIN | c.1216G>A p.A406T | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.305); catalogued as COSV58723910; called by muse, mutect2, varscan2
- CCT8 | c.1351G>A p.A451T | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.089); catalogued as rs892474753, COSV54502811; called by muse, mutect2, varscan2
- CD4 | c.498dup p.K167Efs*13 | Frame Shift Ins (INS) | VAF 19/120 reads (16%) | catalogued as rs781937995; called by mutect2, varscan2
- CD93 | c.361del p.E121Rfs*79 | Frame Shift Del (DEL) | VAF 11/24 reads (46%) | catalogued as rs762805003; called by mutect2, varscan2
- CDH13 | c.342del p.D116Tfs*31 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | catalogued as rs1567763530, COSV51808407; called by mutect2, pindel, varscan2
- CDH20 | c.2014G>A p.E672K | Missense Mutation (SNP) | VAF 63/233 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV53003771; called by muse, mutect2, varscan2
- CDH23 | c.5477G>A p.R1826Q | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.939); catalogued as rs780097768, COSV56445883; called by muse, mutect2, varscan2
- CDH24 | c.2135del p.P712Rfs*129 | Frame Shift Del (DEL) | VAF 37/146 reads (25%) | catalogued as rs752398646; called by mutect2, pindel, varscan2
- CDH4 | c.1859C>T p.A620V | Missense Mutation (SNP) | VAF 58/351 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0.374); catalogued as rs138803497; called by muse, mutect2, varscan2
- CDKN2A | c.244G>A p.V82M | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs1060501269, COSV58682703, COSV58715254, COSV58723757; called by muse, mutect2, varscan2
- CDYL | c.847G>A p.G283R (on ENST00000328908 / NM_001368125.1; = p.G229R on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as rs369374629, COSV100189847; called by muse, mutect2, varscan2
- CEACAM1 | c.426G>A p.P142= | Splice Region (SNP) | VAF 54/208 reads (26%) | catalogued as rs756230191, COSV50725329; called by muse, mutect2, varscan2
- CEL | c.499C>T p.R167C (on ENST00000673714; = p.R164C on NM_001807.6) | Missense Mutation (SNP) | VAF 96/906 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1222612097, COSV60826134; called by muse, varscan2
- CEMIP | c.2390G>A p.R797H | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs752233938, COSV54987551; called by muse, mutect2, varscan2
- CENPJ | c.3830G>A p.G1277D | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1566275283, COSV55033188; called by muse, mutect2, varscan2
- CENPO | c.523C>T p.H175Y | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.569); catalogued as COSV53163858; called by muse, mutect2, varscan2
- CEP126 | c.2485C>T p.P829S | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54821184; called by muse, mutect2, varscan2
- CEP170B | c.2452G>T p.G818W (on ENST00000453495; = p.G747W on NM_015005.3) | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1222753945, COSV69023004; called by muse, mutect2, varscan2
- CEP250 | c.137A>G p.Q46R | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.577); catalogued as COSV100698923; called by mutect2, varscan2
- CEP250 | c.4224G>T p.Q1408H | Missense Mutation (SNP) | VAF 7/115 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV61167901; called by muse, mutect2
- CERS1 | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.257); catalogued as COSV55928198; called by muse, mutect2
- CFAP206 | c.1475C>T p.T492I | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.011); catalogued as COSV51532330; called by muse, mutect2, varscan2
- CFAP61 | c.49C>T p.R17* | Nonsense Mutation (SNP) | VAF 24/63 reads (38%) | catalogued as COSV55617779; called by muse, mutect2, varscan2
- CFAP61 | c.2202C>A p.C734* | Nonsense Mutation (SNP) | VAF 26/162 reads (16%) | catalogued as COSV55617801; called by muse, mutect2, varscan2
- CFAP74 | c.860C>T p.A287V | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as rs768950775, COSV54564219; called by muse, mutect2, varscan2
- CFHR1 | c.941G>A p.R314Q | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.299); catalogued as rs1237921506, COSV57625702, COSV57628365; called by muse, mutect2, varscan2
- CHAD | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 42/209 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.781); catalogued as rs142146358; called by muse, mutect2, varscan2
- CHAD | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT tolerated (0.91); PolyPhen benign (0.006); catalogued as rs1318689346, COSV51970789; called by muse, mutect2, varscan2
- CHAF1A | c.2669G>A p.G890D | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.976); catalogued as COSV56669836; called by muse, mutect2, varscan2
- CHD3 | c.5842G>A p.A1948T (on ENST00000330494 / NM_001005273.3; = p.A1914T on NM_005852.4) | Missense Mutation (SNP) | VAF 51/191 reads (27%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as rs1309516500, COSV57872130; called by muse, mutect2, varscan2
- CHFR | c.1516G>A p.A506T (on ENST00000432561 / NM_001161345.1; = p.A465T on NM_018223.2) | Missense Mutation (SNP) | VAF 110/297 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.154); catalogued as rs746554223, COSV57171673; called by muse, mutect2, varscan2
- CHI3L2 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.571); catalogued as COSV63873235; called by muse, mutect2, varscan2
- CHL1 | c.2997G>T p.Q999H (on ENST00000397491 / NM_001253387.1; = p.Q1015H on NM_006614.4) | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.559); catalogued as rs752478426, COSV56585294, COSV56592745; called by muse, mutect2, varscan2
- CHM | c.992C>A p.P331H | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63299977; called by muse, mutect2, varscan2
- CHRM1 | c.709A>G p.S237G | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.168); catalogued as COSV61006050; called by muse, mutect2, varscan2
- CHRM3 | c.1700del p.K567Rfs*31 | Frame Shift Del (DEL) | VAF 17/76 reads (22%) | catalogued as rs751548647; called by mutect2, varscan2
- CHRM4 | c.752A>T p.K251M | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.698); catalogued as COSV100708791; called by muse, mutect2, varscan2
- CHRNA4 | c.1700C>T p.A567V | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.302); catalogued as rs76895198, COSV64718380; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- CKAP2 | c.1817del p.K606Rfs*14 (on ENST00000378037 / NM_001098525.2; = p.K605Rfs*14 on NM_018204.5) | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | catalogued as rs752250702; called by mutect2, varscan2
- CKAP4 | c.785G>A p.S262N | Missense Mutation (SNP) | VAF 58/153 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV65172086, COSV65172796; called by muse, mutect2, varscan2
- CLCN3 | c.877G>A p.G293R | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1406868937, COSV61626102; called by muse, mutect2, varscan2
- CLMN | c.2072del p.P691Qfs*54 | Frame Shift Del (DEL) | VAF 19/92 reads (21%) | catalogued as COSV54179609; called by mutect2, pindel, varscan2
- CNGB1 | c.3143C>T p.A1048V | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs755959274, COSV51897054; called by muse, mutect2, varscan2
- CNTN2 | c.1222G>A p.A408T | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV59347794; called by muse, mutect2, varscan2
- COIL | c.485del p.N162Tfs*47 | Frame Shift Del (DEL) | VAF 22/75 reads (29%) | catalogued as rs769265872; called by mutect2, varscan2
- COL11A1 | c.1082A>G p.E361G | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs372451206; called by muse, mutect2, varscan2
- COL11A2 | c.4055C>T p.P1352L (on ENST00000341947 / NM_080680.3; = p.P1245L on NM_080679.2) | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as rs763995767, COSV59493121; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL17A1 | c.1493G>A p.R498H | Missense Mutation (SNP) | VAF 44/180 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs371044491, COSV62225589; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL3A1 | c.2020A>G p.K674E | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV58581215; called by muse, mutect2, varscan2
- COL4A2 | c.2038+2T>C p.X680_splice | Splice Site (SNP) | VAF 11/84 reads (13%) | catalogued as COSV64624295; called by muse, mutect2, varscan2
- COL5A3 | c.2200G>A p.G734S | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs556243775, COSV53405293; called by muse, mutect2, varscan2
- COL5A3 | c.1997C>T p.P666L | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV53405298; called by muse, mutect2, varscan2
- COL6A6 | c.2156G>A p.R719Q | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756106307, COSV62016664, COSV62040144; called by muse, mutect2, varscan2
- CORO2B | c.1000G>A p.A334T | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV55949491; called by muse, mutect2, varscan2
- COX11 | c.786dup p.E263* | Frame Shift Ins (INS) | VAF 12/42 reads (29%) | catalogued as rs778099821; called by mutect2, varscan2
- COX20 | c.107A>G p.Y36C | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.105); catalogued as rs754328791, COSV100834672; called by muse, mutect2, varscan2
- CPAMD8 | c.4669G>A p.V1557I (on ENST00000651564; = p.V1510I on NM_015692.5) | Missense Mutation (SNP) | VAF 65/221 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as rs370430527; called by muse, mutect2, varscan2
- CPS1 | c.1145C>T p.P382L | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.28); catalogued as rs201407486, CM114316, COSV51800690, COSV51822651; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPSF1 | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62938700; called by muse, mutect2, varscan2
- CPVL | c.291A>G p.I97M | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.033); catalogued as COSV55298652; called by muse, mutect2, varscan2
- CPXCR1 | c.241C>T p.R81* | Nonsense Mutation (SNP) | VAF 4/19 reads (21%) | catalogued as rs753571924, COSV52160820; called by muse, mutect2
- CR2 | c.624del p.T209Hfs*10 | Frame Shift Del (DEL) | VAF 50/116 reads (43%) | catalogued as rs747832403; called by mutect2, varscan2
- CR2 | c.820A>T p.I274F | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65505879; called by muse, mutect2, varscan2
- CRAT | c.617T>C p.V206A | Missense Mutation (SNP) | VAF 45/210 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.272); catalogued as COSV58875746; called by muse, mutect2, varscan2
- CREBBP | c.3271C>T p.R1091C | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52112685; called by muse, mutect2, varscan2
- CRTC1 | c.1713del p.S572Afs*6 | Frame Shift Del (DEL) | VAF 36/115 reads (31%) | catalogued as rs769538822; called by mutect2, varscan2
- CRYL1 | c.405G>T p.L135F | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV53415866; called by muse, mutect2, varscan2
- CSDE1 | c.1280G>A p.R427H (on ENST00000358528 / NM_001007553.3; = p.R396H on NM_007158.6) | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.412); catalogued as rs763264252, COSV54736543; called by muse, mutect2, varscan2
- CSTL1 | c.187C>T p.R63* | Nonsense Mutation (SNP) | VAF 42/199 reads (21%) | catalogued as rs778469768, COSV55677533; called by muse, mutect2, varscan2
- CTAGE1 | c.2069del p.P690Hfs*30 | Frame Shift Del (DEL) | VAF 26/119 reads (22%) | catalogued as rs766584848; called by mutect2, pindel, varscan2
- CTCFL | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 30/193 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.02); catalogued as rs1445814246, COSV54770226; called by muse, mutect2, varscan2
- CTIF | c.689del p.G230Afs*26 | Frame Shift Del (DEL) | VAF 48/179 reads (27%) | catalogued as rs1381238054, COSV99838187; called by mutect2, pindel, varscan2
- CTNND2 | c.1477G>A p.A493T | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs760066114, COSV58861744; called by muse, mutect2, varscan2
- CUBN | c.9115G>T p.G3039C | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64706908; called by muse, mutect2, varscan2
- CUL1 | c.534+2T>C p.X178_splice | Splice Site (SNP) | VAF 28/142 reads (20%) | catalogued as COSV57386424; called by muse, mutect2, varscan2
- CUL7 | c.3973C>T p.Q1325* | Nonsense Mutation (SNP) | VAF 41/196 reads (21%) | catalogued as COSV54812698; called by muse, mutect2, varscan2
- CUX1 | c.1375G>A p.E459K (on ENST00000437600 / NM_181500.4; = p.E461K on NM_001913.5) | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.848); catalogued as rs782181844, COSV99475547; called by muse, mutect2, varscan2
- CUX2 | c.569A>G p.Q190R | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV55622989; called by muse, mutect2, varscan2
- CYB5A | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 76/240 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs956228194, COSV55021345; called by muse, mutect2, varscan2
- CYB5R4 | c.115C>T p.R39* | Nonsense Mutation (SNP) | VAF 8/42 reads (19%) | catalogued as rs1320230000, COSV63745864, COSV63746888; called by muse, mutect2, varscan2
- CYC1 | c.931T>C p.W311R | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1316309190, COSV59643599; called by muse, mutect2, varscan2
- CYP19A1 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.052); catalogued as rs76174961; called by muse, mutect2, varscan2
- CYP21A2 | c.1063C>T p.R355C | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs772900496, CM000366, COSV64472497; called by muse, mutect2, varscan2
- CYP4A11 | c.977C>T p.T326I | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.612); catalogued as rs1229530724, COSV60226500; called by muse, mutect2, varscan2
- CYSLTR1 | c.657del p.K219Nfs*3 | Frame Shift Del (DEL) | VAF 5/29 reads (17%) | catalogued as rs35745545; called by mutect2, pindel, varscan2
- CYTH3 | c.799C>T p.R267C | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs781110781, COSV63437211; called by muse, mutect2, varscan2
- DAO | c.34G>A p.G12R | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373913310, COSV57321201; called by muse, mutect2, varscan2
- DAPK1 | c.2798C>T p.A933V | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV63783628; called by muse, mutect2, varscan2
- DAXX | c.712C>T p.R238* | Nonsense Mutation (SNP) | VAF 27/93 reads (29%) | catalogued as rs1402930433, COSV56466141; called by muse, mutect2, varscan2
- DCLK1 | c.829C>T p.R277* | Nonsense Mutation (SNP) | VAF 38/140 reads (27%) | catalogued as COSV55169725; called by muse, mutect2, varscan2
- DCLK3 | c.980C>T p.T327M | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs767622640, COSV69362121; called by muse, mutect2, varscan2
- DCST2 | c.1604G>A p.R535Q | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.341); catalogued as rs150983219; called by muse, mutect2, varscan2
- DDO | c.875C>T p.A292V (on ENST00000368924 / NM_001368172.1; = p.A233V on NM_004032.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs140929618, COSV64469586; called by muse, mutect2, varscan2
- DDX10 | c.238del p.T80Hfs*2 | Frame Shift Del (DEL) | VAF 8/35 reads (23%) | catalogued as rs1176416201; called by mutect2, pindel, varscan2
- DDX11 | c.1198G>A p.D400N | Missense Mutation (SNP) | VAF 57/212 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756846997, COSV52499087; called by muse, mutect2, varscan2
- DDX11 | c.2200_2202del p.K734del | In Frame Del (DEL) | VAF 17/59 reads (29%) | catalogued as rs1555224465; called by pindel, varscan2
- DDX31 | c.532del p.M178Cfs*42 | Frame Shift Del (DEL) | VAF 22/102 reads (22%) | catalogued as rs1352828170; called by mutect2, pindel, varscan2
- DEAF1 | c.493G>T p.G165C | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV58605576; called by muse, mutect2, varscan2
- DEFB1 | c.127C>T p.Q43* | Nonsense Mutation (SNP) | VAF 17/46 reads (37%) | catalogued as COSV52412625; called by muse, mutect2, varscan2
- DEK | c.863G>C p.S288T | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV55236368; called by muse, mutect2, varscan2
- DENND5A | c.2684del p.K895Sfs*7 | Frame Shift Del (DEL) | VAF 14/80 reads (18%) | catalogued as rs1208100549; called by mutect2, pindel, varscan2
- DGKI | c.2752G>A p.V918M | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs753942158, COSV55934610; called by muse, mutect2, varscan2
- DGKZ | c.1625del p.G542Afs*17 (on ENST00000454345 / NM_001105540.2; = p.G354Afs*17 on NM_003646.4) | Frame Shift Del (DEL) | VAF 18/71 reads (25%) | catalogued as COSV100552143, COSV58988416; called by mutect2, pindel, varscan2
- DHRS4 | c.232G>T p.G78W | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as COSV57479718; called by muse, mutect2, varscan2
- DHX35 | c.998G>A p.R333H | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV52667107; called by muse, mutect2, varscan2
- DHX37 | c.1793C>T p.A598V | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as COSV100439231, COSV58135142; called by muse, mutect2
- DIP2B | c.3802G>A p.V1268M | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.026); catalogued as rs1257807545, COSV99998492; called by muse, mutect2, varscan2
- DIP2C | c.3088G>A p.V1030M | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55144608; called by muse, mutect2, varscan2
- DIP2C | c.2384G>A p.G795D | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.91); catalogued as COSV55144615; called by muse, mutect2, varscan2
- DIS3L | c.1906G>T p.A636S (on ENST00000319212 / NM_001143688.3; = p.A553S on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.867); catalogued as COSV59910845; called by muse, mutect2, varscan2
- DKC1 | c.736C>A p.L246I | Missense Mutation (SNP) | VAF 45/169 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV65776896; called by muse, mutect2, varscan2
- DKK2 | c.29C>T p.S10L | Missense Mutation (SNP) | VAF 40/156 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as COSV53393370; called by muse, mutect2, varscan2
- DLK2 | c.992C>A p.A331D | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.125); catalogued as rs749317638, COSV55084115; called by muse, mutect2, varscan2
- DLL1 | c.845dup p.L283Pfs*14 | Frame Shift Ins (INS) | VAF 18/85 reads (21%) | catalogued as rs760008381; called by mutect2, varscan2
- DMD | c.8887G>A p.V2963M | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756567967, COSV58889097, COSV58899060; called by muse, mutect2, varscan2
- DNAH1 | c.9815G>A p.R3272H | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs767373969, COSV70225887; called by muse, mutect2, varscan2
- DNAH11 | c.3958C>T p.R1320C | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs753807678, COSV60937289; called by muse, mutect2, varscan2
- DNAJC13 | c.1952T>C p.L651S | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53444932; called by muse, mutect2, varscan2
- DNHD1 | c.13736G>A p.R4579H | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as rs770319879, COSV54429524; called by muse, mutect2, varscan2
- DOCK10 | c.1272del p.F424Lfs*2 | Frame Shift Del (DEL) | VAF 23/96 reads (24%) | catalogued as rs1559599687; called by mutect2, pindel, varscan2
- DOCK10 | c.554C>T p.S185F | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV51346773; called by muse, mutect2, varscan2
- DPEP1 | c.1220G>A p.C407Y | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs748039332, COSV55358725; called by muse, mutect2, varscan2
- DPYD | c.1121C>A p.P374H | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64589600; called by muse, mutect2, varscan2
- DRC7 | c.1292G>A p.R431H | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.135); catalogued as rs752663613, COSV61052774; called by muse, mutect2, varscan2
- DSC1 | c.2546C>T p.S849L | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.435); catalogued as rs754736071, COSV57141217; called by muse, mutect2, varscan2
- DSP | c.8053G>A p.A2685T | Missense Mutation (SNP) | VAF 70/268 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.215); catalogued as COSV60938467; called by muse, mutect2, varscan2
- DUSP16 | c.1063G>A p.V355M | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs370409500; called by muse, mutect2, varscan2
- DYNC1LI1 | c.999A>G p.I333M | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs955005101, COSV56126719; called by muse, mutect2, varscan2
- ECI1 | c.553G>A p.A185T | Missense Mutation (SNP) | VAF 43/173 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); catalogued as rs766030120, COSV57042627; called by muse, mutect2, varscan2
- ECPAS | c.3410C>T p.T1137I | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as COSV52190720; called by muse, mutect2, varscan2
- EED | c.337T>C p.F113L | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV54552847; called by muse, mutect2, varscan2
- EEFSEC | c.1651C>T p.R551W | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as rs766932952, COSV54619242; called by muse, mutect2, varscan2
- EIF2B4 | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.353); catalogued as COSV52006164; called by muse, mutect2
- EIF3A | c.4097G>A p.R1366H | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs143903271; called by mutect2, varscan2
- EIF3C | c.913C>T p.R305W | Missense Mutation (SNP) | VAF 90/738 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.381); catalogued as rs757977079, COSV59059648; called by muse, mutect2, varscan2
- EIF4A2 | c.682T>A p.F228I | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.123); catalogued as COSV56215280; called by muse, mutect2, varscan2
- EIF4G1 | c.3865C>T p.R1289C (on ENST00000346169 / NM_198241.3; = p.R1094C on NM_004953.5) | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1023578171, COSV59988689; called by muse, mutect2, varscan2
- EIF5A | c.338G>A p.R113H | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.4); catalogued as COSV59746680; called by muse, mutect2, varscan2
- EIF5B | c.3523C>T p.H1175Y | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as COSV51481430; called by muse, mutect2, varscan2
- ELOA | c.1394del p.N465Mfs*19 | Frame Shift Del (DEL) | VAF 30/148 reads (20%) | catalogued as rs766700925; called by mutect2, varscan2
- ENOSF1 | c.1432T>C p.*478Qext*21 (on ENST00000340116 / NM_001354066.2; = p.*444Qext*21 on NM_017512.7 and 1 other RefSeq transcript) | Nonstop Mutation (SNP) | VAF 65/268 reads (24%) | catalogued as COSV51890195; called by muse, mutect2, varscan2
- EP400 | c.2600C>T p.A867V | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); catalogued as rs1224276534, COSV57761435; called by mutect2, varscan2
- EPB41 | c.2176G>T p.G726* (on ENST00000343067 / NM_001166005.2; = p.G484* on NM_004437.4) | Nonsense Mutation (SNP) | VAF 7/40 reads (18%) | catalogued as COSV58040165; called by muse, mutect2, varscan2
- EPB41L3 | c.2510C>T p.T837M | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.097); catalogued as rs143141379; called by muse, mutect2, varscan2
- EPB41L5 | c.802del p.W268Gfs*4 | Frame Shift Del (DEL) | VAF 10/32 reads (31%) | catalogued as rs35675992; called by mutect2, pindel, varscan2
- EPN2 | c.1408del p.T470Qfs*5 | Frame Shift Del (DEL) | VAF 18/69 reads (26%) | catalogued as rs756461692; called by mutect2, varscan2
- EPO | c.293C>T p.S98L | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as rs765261245, COSV53160940; called by muse, mutect2, varscan2
- EPRS1 | c.1445G>A p.R482H | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs995368212, COSV65096956; called by muse, mutect2, varscan2
- ERCC1 | c.835C>A p.P279T | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV50003596; called by muse, mutect2, varscan2
- ERI3 | c.913C>T p.R305W | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750266605, COSV64830012; called by muse, mutect2, varscan2
- ERMP1 | c.1951del p.T651Pfs*3 | Frame Shift Del (DEL) | VAF 11/40 reads (28%) | catalogued as rs753821453; called by mutect2, varscan2
- ESPNL | c.823del p.L275Sfs*16 | Frame Shift Del (DEL) | VAF 10/42 reads (24%) | catalogued as rs1309653898; called by mutect2, pindel, varscan2
- ETV4 | c.399del p.R134Dfs*30 | Frame Shift Del (DEL) | VAF 10/49 reads (20%) | catalogued as rs745944421, COSV60043782; called by mutect2, pindel, varscan2
- EVC | c.1979C>T p.T660M | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.799); catalogued as rs550100215, COSV53828779; called by muse, mutect2, varscan2
- EVPL | c.655T>G p.S219A | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs752117730, COSV56906732; called by muse, mutect2
- FAM161B | c.923T>C p.I308T (on ENST00000651776; = p.I245T on NM_152445.3) | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.944); catalogued as COSV54100698; called by muse, mutect2, varscan2
- FAM171B | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59000328, COSV59000841; called by muse, mutect2, varscan2
- FAM214B | c.124del p.A42Rfs*25 | Frame Shift Del (DEL) | VAF 6/29 reads (21%) | catalogued as rs746881923; called by mutect2, pindel, varscan2
- FAM78A | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as rs780076193, COSV64844261; called by muse, mutect2, varscan2
- FANCA | c.1565A>G p.K522R | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV66879943; called by muse, mutect2, varscan2
- FASTKD1 | c.10dup p.T4Nfs*34 | Frame Shift Ins (INS) | VAF 7/24 reads (29%) | catalogued as rs771228336; called by mutect2, varscan2
- FBXL19 | c.1822G>A p.A608T | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as rs770828332, COSV57940439; called by muse, mutect2, varscan2
- FBXL22 | c.65_67del p.S22del | In Frame Del (DEL) | VAF 15/66 reads (23%) | catalogued as rs757568276; called by mutect2, pindel, varscan2
- FBXL7 | c.773G>A p.R258Q | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as rs189208873; called by muse, mutect2, varscan2
- FBXO31 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (1); PolyPhen probably damaging (0.992); catalogued as COSV61147423; called by muse, mutect2, varscan2
- FBXO40 | c.1114C>T p.P372S | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as rs777647610, COSV57521629; called by muse, mutect2, varscan2
- FCGRT | c.320del p.G107Efs*29 | Frame Shift Del (DEL) | VAF 13/47 reads (28%) | catalogued as rs1568698688; called by mutect2, pindel, varscan2
- FCSK | c.454G>A p.D152N | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773981829, COSV55367346; called by muse, mutect2, varscan2
- FES | c.1048C>T p.R350W | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs771770891, COSV100183520, COSV60996145; called by muse, mutect2, varscan2
- FEV | c.211G>T p.G71C | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV55386126; called by muse, mutect2, varscan2
- FGF14 | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 35/140 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as rs768229163, COSV65934645; called by muse, mutect2, varscan2
- FILIP1L | c.1838A>T p.K613I (on ENST00000354552 / NM_182909.3; = p.K373I on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.456); catalogued as COSV58764320; called by muse, mutect2, varscan2
- FLRT2 | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.093); catalogued as rs765614375, COSV58135562; called by muse, mutect2, varscan2
- FMNL2 | c.1817T>C p.V606A | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.774); catalogued as COSV56489377; called by muse, mutect2, varscan2
- FOXB2 | c.1280C>T p.S427L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.629); catalogued as COSV65022353; called by muse, mutect2, varscan2
- FOXJ3 | c.758C>T p.P253L | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as rs751295614, COSV62359690; called by muse, mutect2, varscan2
- FOXM1 | c.1181C>T p.S394L | Missense Mutation (SNP) | VAF 41/191 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as rs552947229, COSV61205094; called by muse, mutect2, varscan2
- FPR1 | c.739G>A p.A247T | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as rs764370052, COSV59050822; called by muse, mutect2, varscan2
- FRMD5 | c.429G>A p.A143= | Splice Region (SNP) | VAF 20/62 reads (32%) | catalogued as rs568248384, COSV68720082; called by muse, mutect2, varscan2
- FRY | c.5695G>T p.E1899* | Nonsense Mutation (SNP) | VAF 13/49 reads (27%) | catalogued as COSV66564396; called by muse, mutect2, varscan2
- FRY | c.8674G>A p.A2892T | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0.029); catalogued as rs540098914, COSV66510786; called by muse, mutect2, varscan2
- FSTL1 | c.718T>C p.Y240H | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1313366339, COSV55231713; called by muse, mutect2, varscan2
- FSTL4 | c.2369del p.G790Vfs*6 | Frame Shift Del (DEL) | VAF 19/67 reads (28%) | catalogued as rs765771244; called by mutect2, pindel, varscan2
- FSTL5 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.075); catalogued as COSV60179142; called by muse, mutect2, varscan2
- FTCD | c.521C>T p.T174M | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs757064013, COSV52422890; called by muse, mutect2, varscan2
- FXR1 | c.371del p.N124Ifs*14 | Frame Shift Del (DEL) | VAF 8/48 reads (17%) | catalogued as rs756304971; called by mutect2, varscan2
- FXR2 | c.1816C>T p.R606C | Missense Mutation (SNP) | VAF 73/304 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.586); catalogued as rs751283911, COSV51467342, COSV51467419; called by muse, mutect2, varscan2
- FZD10 | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 47/212 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs778357040, COSV57471920; called by muse, mutect2, varscan2
- FZD7 | c.1624A>G p.I542V | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.919); catalogued as COSV53807989; called by muse, mutect2, varscan2
- FZR1 | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 44/153 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0.011); catalogued as rs962912288, COSV58050051; called by muse, mutect2, varscan2
- G2E3 | c.710G>T p.R237I | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.797); catalogued as COSV52838265; called by muse, mutect2, varscan2
- GABBR2 | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as COSV52292175; called by muse, mutect2, varscan2
- GABRA2 | c.1026G>A p.W342* | Nonsense Mutation (SNP) | VAF 22/73 reads (30%) | catalogued as COSV62911384; called by muse, mutect2, varscan2
- GABRD | c.1049C>T p.P350L | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs759215834, COSV66079789; called by muse, mutect2, varscan2
- GALNT14 | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1457685902, COSV61102033; called by muse, mutect2, varscan2
- GALNT5 | c.1117C>A p.P373T | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV52035559; called by muse, mutect2, varscan2
- GBP7 | c.757C>T p.R253* | Nonsense Mutation (SNP) | VAF 13/59 reads (22%) | catalogued as rs138285876, COSV54007911, COSV54008582; called by muse, mutect2, varscan2
- GCC1 | c.1730G>A p.R577H | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs374524039, COSV58461667; called by muse, mutect2, varscan2
- GCK | c.1190G>A p.R397H | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as CM057328, COSV99789988; called by muse, varscan2
- GDF6 | c.1102T>G p.W368G | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV104380052, COSV54622449; called by muse, mutect2, varscan2
- GDI1 | c.356T>C p.V119A | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV63895134; called by muse, mutect2, varscan2
- GIT2 | c.1727G>A p.R576Q | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs763696895, COSV58077730, COSV58078601; called by muse, mutect2
- GJA5 | c.898C>T p.Q300* | Nonsense Mutation (SNP) | VAF 28/124 reads (23%) | catalogued as COSV54782716; called by muse, mutect2, varscan2
- GLI3 | c.3107C>T p.A1036V | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs774552566, COSV67884673; called by muse, mutect2, varscan2
- GLRA2 | c.1096C>T p.R366C | Missense Mutation (SNP) | VAF 87/373 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.684); catalogued as COSV54335383, COSV54338436; called by muse, mutect2, varscan2
- GLRX | c.208-3dup | Splice Region (INS) | VAF 11/50 reads (22%) | catalogued as rs1210959484; called by mutect2, pindel
- GLT1D1 | c.878A>C p.Q293P (on ENST00000442111 / NM_001366889.1; = p.Q213P on NM_144669.3) | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs1437845662, COSV55877904, COSV55880621; called by muse, mutect2, varscan2
- GNA13 | c.183G>C p.K61N | Missense Mutation (SNP) | VAF 36/176 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71474329; called by muse, mutect2, varscan2
- GNAS | c.844G>A p.G282S | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.003); catalogued as COSV58326333; called by muse, mutect2
- GNAZ | c.612dup p.Q205Afs*35 | Frame Shift Ins (INS) | VAF 51/218 reads (23%) | catalogued as rs752075537; called by mutect2, varscan2
- GNL2 | c.2027C>T p.A676V | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs771823024, COSV56168977, COSV56171540; called by muse, mutect2, varscan2
- GOT1L1 | c.1243del p.T415Hfs*2 | Frame Shift Del (DEL) | VAF 20/66 reads (30%) | catalogued as rs370114090; called by mutect2, varscan2
- GP9 | c.275G>A p.S92N | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.093); catalogued as rs780057910, COSV56623710; called by muse, mutect2, varscan2
- GPATCH8 | c.2833C>T p.R945* | Nonsense Mutation (SNP) | VAF 29/111 reads (26%) | catalogued as COSV59192931, COSV59196980; called by muse, mutect2, varscan2
- GPR157 | c.856G>A p.V286I | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs767167550, COSV66232918; called by muse, mutect2, varscan2
- GPR160 | c.868A>G p.T290A | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as COSV63472498; called by muse, mutect2, varscan2
- GPR173 | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs372615346, COSV60233102; called by muse, mutect2, varscan2
- GPR4 | c.1064T>C p.L355P | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV59916038; called by muse, mutect2, varscan2
- GRINA | c.72del p.Q26Sfs*142 | Frame Shift Del (DEL) | VAF 7/31 reads (23%) | catalogued as rs781965675; called by mutect2, pindel, varscan2
- GRIP2 | c.940G>T p.A314S (on ENST00000619221; = p.A217S on NM_001080423.4) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.81); PolyPhen probably damaging (0.999); catalogued as COSV56119412; called by muse, mutect2
- GRK1 | c.632C>T p.A211V | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.799); catalogued as rs372061074; called by muse, mutect2, varscan2
- GRM2 | c.433A>G p.S145G | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56583026; called by muse, mutect2, varscan2
- GRM2 | c.973A>G p.S325G | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV56583039; called by muse, mutect2, varscan2
- GRM8 | c.2158dup p.H720Pfs*5 | Frame Shift Ins (INS) | VAF 9/49 reads (18%) | catalogued as rs772717214; called by mutect2, varscan2
- GRM8 | c.2040del p.K681Rfs*17 | Frame Shift Del (DEL) | VAF 14/78 reads (18%) | catalogued as COSV58806754; called by pindel, varscan2
- GSTT2B | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); catalogued as rs750357703; called by mutect2, varscan2
- GTF3C5 | c.820A>G p.S274G | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.833); catalogued as COSV59598631; called by muse, mutect2, varscan2
- GZF1 | c.1129T>C p.F377L | Missense Mutation (SNP) | VAF 31/196 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as COSV57634550; called by muse, mutect2, varscan2
- H1-7 | c.299C>A p.P100H | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.871); catalogued as COSV58601593; called by muse, mutect2, varscan2
- H4C6 | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.317); catalogued as rs1404096777, COSV66685368; called by muse, mutect2, varscan2
- H4C9 | c.77A>G p.N26S | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.325); catalogued as rs753685066, COSV62889549; called by muse, mutect2, varscan2
- HCCS | c.590G>A p.R197Q | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as rs776172899, COSV58238736; called by muse, mutect2, varscan2
- HCRTR2 | c.32del p.P11Lfs*11 | Frame Shift Del (DEL) | VAF 35/156 reads (22%) | catalogued as rs755844571, COSV63794110; called by mutect2, pindel, varscan2
- HDAC10 | c.1948C>A p.L650M | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs755284115, COSV50536150; called by mutect2, varscan2
- HDAC11 | c.920G>A p.R307H | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.096); catalogued as rs1329390256, COSV55472225; called by muse, mutect2, varscan2
- HDAC4 | c.1654G>A p.A552T | Missense Mutation (SNP) | VAF 39/213 reads (18%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs373617636; called by muse, mutect2, varscan2
- HDHD3 | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as rs769615094, COSV53056440; called by muse, mutect2, varscan2
- HEATR6 | c.502T>G p.L168V | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51743432; called by muse, mutect2, varscan2
- HELZ | c.5701C>T p.R1901W | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs201212218; called by muse, mutect2, varscan2
- HERC2 | c.2632G>A p.V878M | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs199898039, COSV55305339, COSV55357236; called by muse, mutect2, varscan2
- HEXB | c.985A>T p.T329S | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV54666736; called by muse, mutect2, varscan2
- HGF | c.1651C>T p.H551Y | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (1); PolyPhen probably damaging (0.997); catalogued as COSV55947080; called by muse, mutect2, varscan2
- HGFAC | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.104); catalogued as rs554424799, COSV58748363; called by muse, mutect2, varscan2
- HIPK2 | c.1493G>A p.R498Q | Missense Mutation (SNP) | VAF 28/167 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs959126759, COSV61225225; called by muse, mutect2, varscan2
- HIPK4 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 46/214 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as rs1568698585, COSV52518848; called by muse, mutect2, varscan2
- HLA-F | c.724G>T p.G242W | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as COSV52574403; called by muse, mutect2, varscan2
- HNRNPAB | c.991C>T p.P331S (on ENST00000504898; = p.P284S on NM_004499.4) | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57422708; called by muse, mutect2, varscan2
- HNRNPM | c.1454G>A p.R485H | Missense Mutation (SNP) | VAF 37/157 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.382); catalogued as COSV55311530; called by muse, mutect2, varscan2
- HOMEZ | c.1127del p.L376Yfs*14 | Frame Shift Del (DEL) | VAF 13/62 reads (21%) | catalogued as rs755016625; called by mutect2, varscan2
- HPR | c.758C>T p.T253M | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as rs764873631, COSV57181354; called by muse, mutect2, varscan2
- HPS4 | c.680C>T p.T227M | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs201806802, COSV61102388, COSV61106359; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HRH4 | c.1162G>T p.V388L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as COSV99907856; called by mutect2, varscan2
- HRNR | c.2644C>T p.R882* | Nonsense Mutation (SNP) | VAF 36/181 reads (20%) | catalogued as rs201064839, COSV64253633; called by muse, mutect2, varscan2
- HSDL1 | c.409C>T p.R137* | Nonsense Mutation (SNP) | VAF 48/157 reads (31%) | catalogued as rs868188543, COSV54740146, COSV54741723; called by muse, mutect2, varscan2
- HTR1E | c.801del p.F268Sfs*5 | Frame Shift Del (DEL) | VAF 46/207 reads (22%) | catalogued as rs753568078, COSV59508996, COSV59509296; called by mutect2, pindel, varscan2
- HTR3A | c.784G>A p.V262M | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.073); catalogued as rs967772544, COSV55467736; called by muse, mutect2, varscan2
- HTR3E | c.610G>A p.A204T (on ENST00000415389 / NM_001256613.1; = p.A219T on NM_182589.2) | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs371514444, COSV58945737; called by muse, mutect2, varscan2
- HYDIN | c.6643G>A p.V2215M | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs555322962, COSV59248366, COSV59264356; called by muse, mutect2, varscan2
- HYKK | c.662G>A p.C221Y | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV66459464, COSV66459633; called by muse, mutect2
- ICE2 | c.1286C>T p.T429I | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV55029456; called by muse, mutect2, varscan2
- IFI44L | c.1232A>G p.D411G | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.689); catalogued as rs1228161019, COSV60726482; called by muse, mutect2, varscan2
- IGLON5 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.746); catalogued as rs779810845, COSV54536211, COSV54536292; called by muse, mutect2, varscan2
- IGSF10 | c.2342del p.P781Qfs*34 | Frame Shift Del (DEL) | VAF 18/83 reads (22%) | catalogued as rs766257083; called by mutect2, pindel, varscan2
- IHH | c.599C>T p.T200M | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs200082799, COSV55392639; called by muse, mutect2, varscan2
- IL22 | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.847); catalogued as rs1440363714, COSV60159669; called by muse, mutect2, varscan2
- IL31RA | c.2065C>A p.L689I | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.025); catalogued as COSV61692177; called by muse, mutect2, varscan2
- IMPA1 | c.121G>T p.D41Y | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56270128; called by muse, mutect2, varscan2
- INO80B | c.1037C>A p.P346H | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.839); catalogued as COSV51967863; called by muse, mutect2, varscan2
- INSC | c.188C>A p.P63Q | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV65408553, COSV65410359; called by muse, mutect2, varscan2
- INSL4 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV53328580; called by muse, mutect2, varscan2
- IQGAP3 | c.4889G>A p.R1630Q | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs140982853, COSV63255255, COSV63255308; called by muse, mutect2
- IRX6 | c.944G>A p.R315H | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV51858898; called by muse, mutect2, varscan2
- ISG20L2 | c.865dup p.L289Pfs*6 | Frame Shift Ins (INS) | VAF 26/118 reads (22%) | catalogued as rs761558950; called by mutect2, varscan2
- ITGA1 | c.1563G>T p.E521D | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV50876255; called by muse, mutect2, varscan2
- ITGA11 | c.3217C>T p.R1073W | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as rs371549494; called by muse, mutect2, varscan2
- ITGAE | c.3343G>A p.V1115I | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs186636209, COSV53988742; called by muse, mutect2, varscan2
- ITGBL1 | c.368G>T p.G123V | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101095362; called by muse, mutect2, varscan2
- ITPR3 | c.6139C>T p.R2047C | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs760282940, COSV65407691; called by muse, mutect2, varscan2
- ITPRIP | c.146A>G p.Q49R | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV53390135; called by muse, mutect2, varscan2
- ITSN1 | c.472dup p.L158Pfs*3 | Frame Shift Ins (INS) | VAF 20/92 reads (22%) | catalogued as rs751926247; called by mutect2, varscan2
- IZUMO4 | c.92_94del p.F31del | In Frame Del (DEL) | VAF 18/83 reads (22%) | catalogued as rs772581359; called by mutect2, pindel, varscan2
- JAG2 | c.3143C>T p.A1048V | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.168); catalogued as rs1487821709, COSV59305982; called by muse, mutect2, varscan2
- JAKMIP2 | c.2293T>C p.Y765H | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.51); PolyPhen benign (0.282); catalogued as COSV54596803, COSV54598546; called by muse, mutect2, varscan2
- KANK4 | c.1319T>C p.M440T | Missense Mutation (SNP) | VAF 61/227 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62985221; called by muse, mutect2, varscan2
- KCNA4 | c.1286del p.G429Vfs*53 | Frame Shift Del (DEL) | VAF 20/107 reads (19%) | catalogued as rs1258313537; called by mutect2, pindel, varscan2
- KCNB2 | c.128del p.G43Afs*40 | Frame Shift Del (DEL) | VAF 32/139 reads (23%) | catalogued as COSV73053085; called by mutect2, pindel, varscan2
- KCNC4 | c.1211G>A p.R404H | Missense Mutation (SNP) | VAF 40/170 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV63924872; called by muse, mutect2, varscan2
- KCNG4 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57582537; called by muse, mutect2, varscan2
- KCNH2 | c.1580C>T p.A527V | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV51125763, COSV51218114; called by muse, mutect2, varscan2
- KCNJ4 | c.22G>A p.G8S | Missense Mutation (SNP) | VAF 180/369 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.078); catalogued as COSV57856001; called by muse, mutect2, varscan2
- KCNK10 | c.1136G>A p.R379Q | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT tolerated (0.66); PolyPhen benign (0.005); catalogued as rs772601324, COSV56638819; called by muse, mutect2, varscan2
- KCNK10 | c.768G>C p.K256N | Missense Mutation (SNP) | VAF 47/185 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV56638844; called by muse, mutect2, varscan2
- KCNMA1 | c.2306del p.K769Sfs*17 (on ENST00000286628 / NM_001161352.2; = p.K711Sfs*17 on NM_002247.4) | Frame Shift Del (DEL) | VAF 10/51 reads (20%) | catalogued as rs771351714; called by mutect2, varscan2
- KCNQ2 | c.1955del p.P652Rfs*278 (on ENST00000359125 / NM_172107.4; = p.P624Rfs*278 on NM_004518.6) | Frame Shift Del (DEL) | VAF 15/94 reads (16%) | catalogued as COSV60550914; called by mutect2, pindel, varscan2
- KCNT1 | c.1273C>T p.R425* (on ENST00000488444; = p.R444* on NM_020822.3) | Nonsense Mutation (SNP) | VAF 12/31 reads (39%) | catalogued as rs764562570, COSV53694931; called by muse, mutect2, varscan2
- KCTD16 | c.910G>A p.G304S | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); catalogued as rs139920765; called by muse, mutect2, varscan2
- KCTD20 | c.1009G>T p.G337C | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54801886; called by muse, mutect2, varscan2
- KCTD21 | c.17C>T p.T6M | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs772092002, COSV60740677; called by muse, mutect2, varscan2
- KCTD9 | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as COSV55338997; called by muse, mutect2, varscan2
- KDM2B | c.77del p.K26Rfs*81 | Frame Shift Del (DEL) | VAF 24/130 reads (18%) | catalogued as rs782541016; called by mutect2, pindel, varscan2
- KHDC1 | c.565C>A p.L189M (on ENST00000370384 / NM_001251874.2; = p.L116M on NM_030568.5) | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as COSV57613993; called by muse, mutect2, varscan2
- KHDRBS3 | c.752del p.P251Qfs*101 | Frame Shift Del (DEL) | VAF 11/53 reads (21%) | catalogued as rs776179021, COSV63421003; called by mutect2, pindel, varscan2
- KIAA1755 | c.2272G>A p.A758T | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1434770399, COSV54073270; called by muse, mutect2, varscan2
- KIF21A | c.3671+2T>C p.X1224_splice (on ENST00000361418 / NM_001378440.1; = p.X1211_splice on NM_017641.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 10/88 reads (11%) | catalogued as rs766785388, COSV62766589; called by muse, varscan2
- KIF23 | c.1165C>T p.R389* | Nonsense Mutation (SNP) | VAF 9/40 reads (23%) | catalogued as COSV52976895; called by muse, mutect2, varscan2
- KIF26B | c.2570G>A p.S857N | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63636011; called by muse, mutect2, varscan2
- KLC2 | c.1708del p.Q570Rfs*8 | Frame Shift Del (DEL) | VAF 24/87 reads (28%) | catalogued as rs1183967253, COSV57581594; called by mutect2, pindel, varscan2
- KLHDC8A | c.658C>A p.L220M | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV65678072; called by muse, mutect2, varscan2
- KLHL34 | c.8A>G p.Y3C | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV65278651; called by muse, mutect2, varscan2
- KLHL35 | c.1040C>T p.A347V | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.086); catalogued as COSV66219083; called by muse, mutect2, varscan2
- KLHL7 | c.899G>C p.G300A (on ENST00000339077 / NM_001031710.3; = p.G252A on NM_018846.5) | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.792); catalogued as COSV59159457; called by muse, mutect2, varscan2
- KLK12 | c.105G>A p.W35* | Nonsense Mutation (SNP) | VAF 3/12 reads (25%) | catalogued as COSV51575475; called by muse, mutect2
- KLK6 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs768388862, COSV59564760; called by muse, mutect2, varscan2
- KMT2C | c.9755G>A p.R3252H | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51274822; called by muse, mutect2, varscan2
- KMT2D | c.14411C>T p.A4804V | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1357291847, COSV56407451; called by muse, mutect2, varscan2
- KMT2D | c.11011C>T p.P3671S | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.997); catalogued as COSV56407469, COSV99040175; called by muse, mutect2, varscan2
- KMT2D | c.2317del p.Q773Sfs*157 | Frame Shift Del (DEL) | VAF 32/106 reads (30%) | catalogued as COSV56443963; called by mutect2, pindel, varscan2
- KMT2E | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV57569025; called by muse, mutect2, varscan2
- KNOP1 | c.957del p.G320Afs*8 | Frame Shift Del (DEL) | VAF 30/138 reads (22%) | catalogued as rs759734033, COSV54927684; called by mutect2, varscan2
- KRI1 | c.1565G>A p.R522H | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57263380; called by muse, mutect2, varscan2
- KRT2 | c.799_800+1del p.X267_splice | Splice Site (DEL) | VAF 24/122 reads (20%) | catalogued as rs1444832290; called by pindel, varscan2
- KRT31 | c.72del p.S25Afs*17 | Frame Shift Del (DEL) | VAF 14/87 reads (16%) | catalogued as COSV52434128; called by mutect2, pindel, varscan2
- KRTAP10-4 | c.977T>C p.V326A | Missense Mutation (SNP) | VAF 81/323 reads (25%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.508); catalogued as COSV59950350; called by muse, mutect2, varscan2
- KRTAP13-4 | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs1250375255, COSV61878454; called by muse, mutect2, varscan2
- KSR2 | c.2468G>A p.R823H | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs183487509, CM1311376; called by muse, mutect2, varscan2
- KSR2 | c.728C>T p.S243L | Missense Mutation (SNP) | VAF 50/103 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs201900914, COSV60364780; called by muse, mutect2, varscan2
- LAMA4 | c.4627A>G p.R1543G (on ENST00000230538 / NM_001105206.3; = p.R1536G on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV57891438; called by muse, mutect2, varscan2
- LAMA5 | c.1645G>A p.A549T | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV53352029; called by muse, mutect2
- LARP1 | c.906del p.T303Pfs*23 (on ENST00000518297 / NM_033551.3; = p.T226Pfs*23 on NM_015315.5 and 6 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 76/316 reads (24%) | catalogued as rs769338468, COSV60425051; called by mutect2, varscan2
- LEPROT | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 43/214 reads (20%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.984); catalogued as rs770318763, COSV100756535, COSV60746319; called by muse, mutect2, varscan2
- LHFPL1 | c.320G>A p.C107Y | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV64332887; called by muse, mutect2, varscan2
- LHX4 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs374124070; called by muse, mutect2, varscan2
- LMAN1L | c.333C>T p.A111= | Splice Region (SNP) | VAF 37/130 reads (28%) | catalogued as rs563585989, COSV59000423; called by muse, mutect2, varscan2
- LMNB1 | c.1228C>T p.R410C | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.207); catalogued as rs955383959, COSV54396395; called by muse, mutect2, varscan2
- LMO7 | c.2206del p.S736Vfs*69 (on ENST00000357063; = p.S417Vfs*69 on NM_005358.5) | Frame Shift Del (DEL) | VAF 14/60 reads (23%) | catalogued as rs34219193; called by mutect2, pindel, varscan2
- LRCH3 | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as rs1427294895, COSV58388275; called by muse, mutect2, varscan2
- LRP1 | c.2032C>T p.R678W | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs1442136139, COSV54500892; called by muse, mutect2, varscan2
- LRP1 | c.2331del p.T778Lfs*2 | Frame Shift Del (DEL) | VAF 27/153 reads (18%) | catalogued as rs34108076; called by mutect2, pindel, varscan2
- LRP1 | c.10588G>T p.E3530* | Nonsense Mutation (SNP) | VAF 52/193 reads (27%) | catalogued as rs1555187720, COSV54500906; called by muse, mutect2, varscan2
- LRP10 | c.812G>A p.G271D | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.82); PolyPhen probably damaging (0.927); catalogued as COSV62077595; called by muse, mutect2, varscan2
- LRP5 | c.2696G>A p.R899H | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53710672; called by muse, mutect2, varscan2
- LRRC4B | c.1201G>A p.G401S | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100976039, COSV65349112; called by muse, mutect2, varscan2
- LRRC6 | c.967G>A p.V323I | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.105); catalogued as COSV51537315; called by muse, mutect2, varscan2
- LRRC7 | c.2992G>A p.V998M (on ENST00000651989 / NM_001370785.2; = p.V965M on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50408871; called by muse, mutect2, varscan2
- LRRC8E | c.1174C>T p.R392C | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs754182382, COSV60716789; called by muse, mutect2, varscan2
- LRRK1 | c.4798-2A>C p.X1600_splice | Splice Site (SNP) | VAF 30/100 reads (30%) | catalogued as COSV52600046; called by muse, mutect2, varscan2
- LRRN1 | c.1708T>C p.Y570H | Missense Mutation (SNP) | VAF 85/337 reads (25%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as rs975402698, COSV60012074; called by muse, mutect2, varscan2
- LRRN3 | c.866T>A p.L289* | Nonsense Mutation (SNP) | VAF 18/99 reads (18%) | catalogued as COSV57817324, COSV57822667; called by muse, mutect2, varscan2
- MACROH2A1 | c.10C>T p.R4C | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV56893025; called by muse, mutect2, varscan2
- MAG | c.112G>A p.V38I | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs757733728, COSV62698732; called by muse, mutect2, varscan2
- MAGI1 | c.2103A>C p.Q701H | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV58312530; called by muse, mutect2, varscan2
- MAGI2 | c.1793C>T p.A598V | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.388); catalogued as COSV62631340; called by muse, mutect2, varscan2
- MAP2 | c.4637C>T p.S1546F | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52279697; called by muse, mutect2, varscan2
- MAP3K13 | c.2638C>T p.R880C | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs572889019, COSV53982703; called by muse, mutect2, varscan2
- MAP3K20 | c.377C>T p.P126L | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100169232, COSV59101294; called by muse, mutect2, varscan2
- MAP7D3 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs747505696, COSV60169921; called by muse, mutect2, varscan2
- MAST2 | c.3071G>A p.R1024H | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.985); catalogued as rs749777352, COSV63615957; called by muse, mutect2, varscan2
- MBD6 | c.2345del p.G782Efs*13 | Frame Shift Del (DEL) | VAF 36/99 reads (36%) | catalogued as rs746267361; called by mutect2, varscan2
- MCM4 | c.1885dup p.T629Nfs*4 | Frame Shift Ins (INS) | VAF 9/45 reads (20%) | catalogued as rs1192152598; called by mutect2, varscan2
- MDN1 | c.15542A>G p.Q5181R | Missense Mutation (SNP) | VAF 62/284 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV65516388; called by muse, mutect2, varscan2
- MED12 | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1222426673, COSV61329412; called by muse, mutect2, varscan2
- MED15 | c.1357del p.Q453Sfs*41 (on ENST00000263205 / NM_001003891.3; = p.Q413Sfs*41 on NM_015889.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 15/42 reads (36%) | catalogued as COSV99487865; called by mutect2, pindel, varscan2
- MED25 | c.535C>A p.H179N | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.44); PolyPhen benign (0.334); catalogued as COSV57202644; called by muse, varscan2
- METAP1D | c.962C>T p.T321M | Missense Mutation (SNP) | VAF 71/276 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59928674; called by muse, mutect2, varscan2
- MEX3D | c.931G>A p.G311R | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV101183464, COSV66311662; called by muse, mutect2, varscan2
- MGAT4C | c.1204C>T p.Q402* | Nonsense Mutation (SNP) | VAF 28/61 reads (46%) | catalogued as COSV59829391; called by muse, mutect2, varscan2
- MGRN1 | c.1402_1404del p.E468del | In Frame Del (DEL) | VAF 11/55 reads (20%) | catalogued as rs768682453; called by pindel, varscan2
- MIA2 | c.1089del p.D364Tfs*8 | Frame Shift Del (DEL) | VAF 7/36 reads (19%) | catalogued as rs538500709; called by mutect2, varscan2
- MICALL1 | c.1442G>A p.R481H | Missense Mutation (SNP) | VAF 32/53 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); catalogued as rs372004472; called by muse, mutect2, varscan2
- MIEF1 | c.241C>T p.R81* | Nonsense Mutation (SNP) | VAF 109/227 reads (48%) | catalogued as rs953150767, COSV57477503; called by muse, mutect2, varscan2
- MINAR1 | c.2104del p.S702Afs*11 | Frame Shift Del (DEL) | VAF 46/188 reads (24%) | catalogued as rs748072217, COSV59581461; called by mutect2, varscan2
- MITF | c.1076G>A p.R359Q (on ENST00000448226 / NM_006722.3; = p.R259Q on NM_000248.4) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as rs762920442, COSV58829453; called by mutect2, varscan2
- MKI67 | c.503C>T p.A168V | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV64072303; called by muse, mutect2, varscan2
- MKI67 | c.239T>C p.V80A | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as COSV64072306; called by muse, mutect2, varscan2
- MKRN3 | c.781C>A p.L261I | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as COSV58808376; called by muse, mutect2, varscan2
- MLF2 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV52570529; called by muse, mutect2, varscan2
- MLX | c.256A>T p.S86C | Missense Mutation (SNP) | VAF 77/271 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV53815928; called by muse, mutect2, varscan2
- MMP14 | c.869C>T p.P290L | Missense Mutation (SNP) | VAF 58/237 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.08); catalogued as COSV61287302; called by muse, mutect2, varscan2
- MMP25 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs377224522; called by muse, mutect2, varscan2
- MMRN2 | c.1618G>A p.V540M | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.817); catalogued as rs757358805, COSV64400320; called by muse, mutect2, varscan2
- MN1 | c.129del p.P45Lfs*8 | Frame Shift Del (DEL) | VAF 23/115 reads (20%) | catalogued as COSV56556167; called by mutect2, pindel, varscan2
- MORC2 | c.1813-3del | Splice Region (DEL) | VAF 8/33 reads (24%) | catalogued as rs777649506, COSV53202254; called by mutect2, varscan2
- MORC4 | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375777883, COSV55239140; called by muse, mutect2, varscan2
- MORN3 | c.305G>A p.G102D | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs1555325502, COSV62506988; called by muse, mutect2, varscan2
- MOXD1 | c.1579T>C p.F527L | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV60941553; called by muse, mutect2, varscan2
- MRE11 | c.1532del p.N511Ifs*13 | Frame Shift Del (DEL) | VAF 7/39 reads (18%) | catalogued as rs757691558; called by mutect2, pindel, varscan2
- MRM3 | c.646A>C p.N216H | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58679146; called by muse, mutect2, varscan2
- MRPL3 | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as rs143919720, COSV99394649; called by muse, mutect2, varscan2
- MRPL48 | c.391A>G p.T131A | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.832); catalogued as COSV58638596; called by muse, mutect2, varscan2
- MSC | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.043); catalogued as rs1230012786, COSV100335849, COSV57696076; called by muse, mutect2, varscan2
- MTCL1 | c.2530C>A p.L844M (on ENST00000306329 / NM_001378206.1; = p.L484M on NM_015210.4) | Missense Mutation (SNP) | VAF 60/205 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.135); catalogued as COSV60402594; called by muse, mutect2, varscan2
- MTOR | c.4847G>A p.R1616H | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs1297595805, COSV63867987; called by muse, mutect2, varscan2
- MTOR | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63867992; called by muse, mutect2, varscan2
- MUC5B | c.8971T>C p.W2991R | Missense Mutation (SNP) | VAF 92/355 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0.04); catalogued as COSV71589693; called by muse, mutect2, varscan2
- MUSK | c.850G>T p.A284S | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV51877178; called by muse, mutect2, varscan2
- MXRA8 | c.901del p.R301Gfs*107 | Frame Shift Del (DEL) | VAF 10/38 reads (26%) | catalogued as rs764857791; called by mutect2, pindel, varscan2
- MYBL2 | c.951G>A p.S317= | Splice Region (SNP) | VAF 15/124 reads (12%) | catalogued as rs774852019, COSV53827321, COSV99406635; called by muse, mutect2, varscan2
- MYH7B | c.2657C>T p.P886L | Missense Mutation (SNP) | VAF 52/249 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53416087; called by muse, mutect2, varscan2
- MYL2 | c.211A>G p.K71E | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.129); catalogued as COSV57405890; called by muse, mutect2, varscan2
- MYO10 | c.3667G>A p.G1223R | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1434873123, COSV57016082, COSV57017061; called by muse, mutect2, varscan2
- MYO10 | c.3299C>A p.A1100D | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.497); catalogued as COSV57016099; called by muse, mutect2, varscan2
- MYO16 | c.1497G>T p.R499S | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV99193891; called by muse, mutect2, varscan2
- MYO5A | c.2368C>T p.R790W | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.223); catalogued as rs764883819, COSV62556163; called by muse, mutect2, varscan2
- MYOCD | c.374dup p.N125Kfs*16 | Frame Shift Ins (INS) | VAF 44/152 reads (29%) | catalogued as rs1567587048; called by mutect2, varscan2
- MYOF | c.4357T>C p.W1453R | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63699641; called by muse, mutect2, varscan2
- MYT1 | c.2326C>G p.P776A | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.241); catalogued as COSV60500284, COSV60512848; called by muse, mutect2
- MYT1 | c.2759C>T p.A920V | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770439955, COSV60500304; called by muse, mutect2, varscan2
- MYT1L | c.1325C>T p.T442M | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs754747899, COSV67706497; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- N4BP1 | c.733T>C p.S245P | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV52209280; called by muse, mutect2, varscan2
- NAA80 | c.269G>A p.R90H (on ENST00000417393 / NM_001200018.2; = p.R112H on NM_012191.4) | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1325251913, COSV56496563; called by muse, mutect2, varscan2
- NAALADL1 | c.985G>T p.A329S | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.84); PolyPhen benign (0.006); catalogued as COSV60522739; called by muse, mutect2, varscan2
- NADSYN1 | c.437T>C p.M146T | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.034); catalogued as COSV59809736; called by muse, mutect2, varscan2
- NBAS | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.763); catalogued as COSV55710966; called by muse, mutect2, varscan2
- NBN | c.2232del p.F744Lfs*7 | Frame Shift Del (DEL) | VAF 4/23 reads (17%) | catalogued as rs1554554233, COSV99620083; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- NCAPG | c.1929G>T p.K643N | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as COSV52268338; called by muse, mutect2, varscan2
- NDUFAF6 | c.337C>T p.R113* | Nonsense Mutation (SNP) | VAF 13/41 reads (32%) | catalogued as rs753873681, COSV54406997; called by muse, mutect2, varscan2
- NDUFS1 | c.1159_1161del p.L387del | In Frame Del (DEL) | VAF 10/37 reads (27%) | catalogued as rs1284748620; called by pindel, varscan2
- NDUFS5 | c.47G>A p.R16Q | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV65892223; called by muse, mutect2, varscan2
- NECTIN4 | c.850C>T p.R284W | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); catalogued as rs375484596; called by muse, mutect2, varscan2
- NEDD4L | c.704A>T p.N235I | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.361); catalogued as COSV56839432; called by muse, mutect2, varscan2
- NEK8 | c.1913G>A p.G638D | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776486944, COSV52042536; called by muse, mutect2, varscan2
- NEXMIF | c.1018A>G p.S340G | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as COSV50021533; called by muse, mutect2, varscan2
- NFATC2 | c.811C>T p.R271C | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.308); catalogued as rs1340389038, COSV65352912, COSV65354656; called by muse, mutect2, varscan2
- NFX1 | c.454_456del p.S152del | In Frame Del (DEL) | VAF 33/113 reads (29%) | catalogued as rs1275704768; called by mutect2, pindel, varscan2
- NHSL2 | c.266C>T p.A89V (on ENST00000510661; = p.A455V on NM_001013627.2) | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1379092819, COSV65452248; called by muse, mutect2, varscan2
- NID2 | c.2026+2T>C p.X676_splice | Splice Site (SNP) | VAF 20/93 reads (22%) | catalogued as COSV53492437; called by muse, mutect2, varscan2
- NIPSNAP1 | c.616C>T p.R206W | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99331138; called by muse, mutect2, varscan2
- NIPSNAP2 | c.547G>A p.G183R | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as rs750178567, COSV59050129; called by muse, mutect2, varscan2
- NIT2 | c.585-1G>A p.X195_splice | Splice Site (SNP) | VAF 28/102 reads (27%) | catalogued as COSV67629972; called by muse, mutect2, varscan2
- NKX6-1 | c.237del p.L80Sfs*23 | Frame Shift Del (DEL) | VAF 4/16 reads (25%) | catalogued as rs745904099; called by mutect2, varscan2
- NLRP7 | c.1274C>T p.A425V | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.591); catalogued as rs1326893606, COSV60170621; called by muse, mutect2, varscan2
- NMT1 | c.1312G>A p.A438T | Missense Mutation (SNP) | VAF 66/268 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.423); catalogued as rs755095071, COSV51958172; called by muse, mutect2, varscan2
- NOP56 | c.1168A>G p.T390A | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as COSV61388597; called by muse, mutect2, varscan2
- NOX3 | c.1643G>A p.C548Y | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV50148487; called by muse, mutect2, varscan2
- NPAP1 | c.227G>T p.R76L | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as COSV61503920, COSV61506368; called by muse, mutect2, varscan2
- NPEPL1 | c.425G>A p.R142Q | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT tolerated (0.61); PolyPhen benign (0.031); catalogued as COSV61937964; called by muse, mutect2, varscan2
- NR0B1 | c.299C>T p.T100M | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.029); catalogued as COSV66763548; called by muse, mutect2, varscan2
- NR2C2 | c.1689del p.F563Lfs*10 (on ENST00000393102; = p.F582Lfs*10 on NM_003298.5) | Frame Shift Del (DEL) | VAF 18/50 reads (36%) | catalogued as rs774343392; called by mutect2, varscan2
- NR3C2 | c.1673A>C p.E558A | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.449); catalogued as COSV60984647; called by muse, mutect2, varscan2
- NRXN1 | c.3935C>T p.A1312V | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as rs201323039, COSV60482055; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NRXN2 | c.3927G>T p.Q1309H | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as COSV55449040, COSV99634091; called by muse, mutect2, varscan2
- NSMAF | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs199548636, COSV50683540; called by muse, mutect2, varscan2
- NUCB1 | c.725G>T p.R242M | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.053); catalogued as COSV99617865; called by muse, mutect2, varscan2
- NUDT11 | c.244G>A p.V82I | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV65664946; called by muse, mutect2, varscan2
- NUP210L | c.2072del p.L691Wfs*3 | Frame Shift Del (DEL) | VAF 8/45 reads (18%) | catalogued as rs760869296; called by mutect2, varscan2
- NUP98 | c.111T>G p.F37L | Missense Mutation (SNP) | VAF 54/191 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as COSV61427950; called by muse, mutect2, varscan2
- OBP2A | c.91G>A p.V31M | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.051); catalogued as rs564413983, COSV100535562; called by muse, mutect2, varscan2
- OBSCN | c.23146G>A p.E7716K | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs990824736, COSV62161127; called by muse, mutect2, varscan2
- OBSL1 | c.2857C>T p.R953C | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.619); catalogued as rs775524938, COSV54703051; called by muse, mutect2, varscan2
- OBSL1 | c.2666C>T p.T889I | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1255037464, COSV54703060, COSV54703204; called by muse, mutect2
- OCA2 | c.1232C>A p.A411D | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1454791644, COSV62337292; called by muse, mutect2, varscan2
- OGFRL1 | c.400+2T>C p.X134_splice | Splice Site (SNP) | VAF 7/34 reads (21%) | catalogued as COSV64971624; called by muse, mutect2, varscan2
- OGT | c.2630G>A p.R877H | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV65479200; called by muse, mutect2, varscan2
- OR10H3 | c.495del p.H166Tfs*9 | Frame Shift Del (DEL) | VAF 18/94 reads (19%) | catalogued as COSV59944080; called by mutect2, pindel, varscan2
- OR2J2 | c.148T>A p.S50T | Missense Mutation (SNP) | VAF 44/167 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as COSV65847664; called by muse, mutect2, varscan2
- OR2L2 | c.849G>A p.M283I | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV63547472; called by muse, varscan2
- OR4K5 | c.535del p.C179Vfs*20 | Frame Shift Del (DEL) | VAF 41/193 reads (21%) | catalogued as rs1566497842; called by mutect2, pindel, varscan2
- OR56A3 | c.226G>A p.V76M | Missense Mutation (SNP) | VAF 38/183 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.133); catalogued as rs957219841, COSV61568454; called by muse, mutect2, varscan2
- OR5B12 | c.385C>T p.H129Y | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.01); catalogued as COSV56903851; called by muse, mutect2, varscan2
- OR5M1 | c.25G>A p.V9M | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as COSV73201941; called by muse, mutect2, varscan2
- OR7G1 | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.794); catalogued as rs769414989, COSV53316818; called by muse, mutect2, varscan2
- OR8H1 | c.622G>A p.V208M | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.043); catalogued as COSV57292861; called by muse, mutect2, varscan2
- OSBP2 | c.1623+2T>C p.X541_splice | Splice Site (SNP) | VAF 37/153 reads (24%) | catalogued as COSV60239152; called by muse, mutect2, varscan2
- OSBPL1A | c.1823C>T p.A608V (on ENST00000319481 / NM_080597.4; = p.A95V on NM_018030.4) | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.625); catalogued as rs750232865, COSV60194785; called by muse, mutect2, varscan2
- OSBPL7 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.877); catalogued as rs201720672; called by muse, mutect2, varscan2
- OSM | c.514dup p.A172Gfs*122 | Frame Shift Ins (INS) | VAF 8/48 reads (17%) | catalogued as rs762184254; called by pindel, varscan2
- OSM | c.497C>T p.T166M | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.595); catalogued as rs200227870, COSV53160649; called by muse, varscan2
- OSMR | c.1849del p.T617Qfs*20 | Frame Shift Del (DEL) | VAF 11/45 reads (24%) | catalogued as rs762315064; called by mutect2, pindel, varscan2
- OSR2 | c.313G>A p.V105I | Missense Mutation (SNP) | VAF 62/236 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as rs372847306; called by muse, mutect2, varscan2
- OTOF | c.3086C>T p.P1029L (on ENST00000272371 / NM_194248.3; = p.P282L on NM_004802.4) | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778011514, COSV55494744; called by muse, mutect2, varscan2
- P2RY4 | c.1012G>T p.V338L | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV65736191; called by muse, mutect2, varscan2
- PANX2 | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs768497136, COSV50291624; called by muse, mutect2, varscan2
- PAPLN | c.1286C>T p.P429L (on ENST00000554301; = p.P402L on NM_173462.4) | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs530218324, COSV53712491; called by muse, mutect2, varscan2
- PAPPA2 | c.5065G>A p.V1689M | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs199980590, COSV62789859; called by muse, mutect2, varscan2
- PARD3B | c.2509del p.T837Rfs*13 (on ENST00000406610 / NM_001302769.2; = p.T768Rfs*13 on NM_057177.7) | Frame Shift Del (DEL) | VAF 17/58 reads (29%) | catalogued as rs772816756; called by mutect2, pindel, varscan2
- PARM1 | c.182A>G p.H61R | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV56649534; called by muse, mutect2, varscan2
- PARP1 | c.1999A>G p.K667E | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV100828889; called by muse, mutect2, varscan2
- PAX1 | c.1212del p.A406Pfs*3 | Frame Shift Del (DEL) | VAF 16/48 reads (33%) | catalogued as rs1555804794; called by mutect2, pindel, varscan2
- PAX3 | c.211G>A p.V71I | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.97); catalogued as rs867285013, COSV51336820; called by muse, mutect2, varscan2
- PCDH15 | c.5627A>G p.Q1876R | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs1301403247, COSV57257450; called by muse, mutect2, varscan2
- PCDHA1 | c.245G>A p.G82D | Missense Mutation (SNP) | VAF 42/192 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs781918697, COSV65372421; called by muse, mutect2, varscan2
- PCDHA7 | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 72/349 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs781827962, COSV65341504; called by muse, varscan2
- PCDHB14 | c.1472T>C p.L491P | Missense Mutation (SNP) | VAF 80/372 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.992); catalogued as COSV53386224; called by muse, mutect2, varscan2
- PCDHB5 | c.2026G>A p.A676T | Missense Mutation (SNP) | VAF 61/228 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.434); catalogued as COSV50647146; called by muse, mutect2, varscan2
- PCDHGA8 | c.1496C>T p.A499V | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.021); catalogued as COSV53892732; called by muse, mutect2, varscan2
- PCDHGB3 | c.781G>A p.V261I | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.376); catalogued as COSV53892713; called by muse, mutect2, varscan2
- PCLO | c.9752T>C p.I3251T | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as rs777690826, COSV61612881; called by muse, mutect2, varscan2
- PCMTD2 | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 50/234 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs375984565; called by muse, mutect2, varscan2
- PCNX3 | c.5693C>A p.P1898H | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.258); catalogued as COSV63134385; called by mutect2, varscan2
- PDCL | c.348T>G p.S116R | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.026); catalogued as COSV52342034; called by muse, mutect2, varscan2
- PDE10A | c.225G>A p.R75= | Splice Region (SNP) | VAF 14/99 reads (14%) | catalogued as COSV63090325; called by muse, mutect2, varscan2
- PDE7B | c.968A>G p.D323G | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57492003; called by muse, mutect2, varscan2
- PDHA2 | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs267600306, COSV54776945; called by muse, mutect2, varscan2
- PDIA5 | c.1030G>A p.A344T | Missense Mutation (SNP) | VAF 43/206 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.42); catalogued as COSV60246892; called by muse, mutect2, varscan2
- PDLIM1 | c.902T>C p.V301A | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61473393; called by muse, mutect2, varscan2
- PHF2 | c.2402T>C p.M801T | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV63678090; called by muse, mutect2, varscan2
- PHF21A | c.137C>A p.A46D | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.655); catalogued as COSV99138533; called by muse, mutect2, varscan2
- PHKA1 | c.1130C>T p.P377L | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.014); catalogued as COSV59801209; called by muse, mutect2, varscan2
- PIGM | c.677C>A p.A226D | Missense Mutation (SNP) | VAF 40/168 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV63635435; called by muse, mutect2, varscan2
- PKD1 | c.7222C>T p.R2408C | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.862); catalogued as rs538769374, CM003335, COSV51909692; called by muse, mutect2, varscan2
- PKDREJ | c.3592G>A p.V1198M | Missense Mutation (SNP) | VAF 75/158 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs780697271, COSV53546158; called by muse, mutect2, varscan2
- PLAAT3 | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs868101877, COSV60310767; called by muse, mutect2, varscan2
- PLAAT4 | c.483del p.A162Rfs*56 | Frame Shift Del (DEL) | VAF 48/186 reads (26%) | catalogued as rs745860467; called by mutect2, varscan2
- PLB1 | c.2474+1G>A p.X825_splice | Splice Site (SNP) | VAF 31/97 reads (32%) | catalogued as rs151120274; called by muse, mutect2, varscan2
- PLCD4 | c.1619T>C p.V540A | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV68742854; called by muse, mutect2, varscan2
- PLD1 | c.3121C>T p.R1041C | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs1275391238, COSV60564949; called by muse, mutect2, varscan2
- PLEKHA1 | c.26G>A p.R9H | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.802); catalogued as rs769179533, COSV64568897; called by muse, mutect2, varscan2
- PLOD3 | c.476C>T p.T159M | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as rs763102265, COSV56181115; called by muse, mutect2, varscan2
- PLXNA1 | c.4150C>T p.R1384C | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs368240880; called by muse, mutect2, varscan2
- PLXNA1 | c.5420C>T p.P1807L | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52521680; called by muse, mutect2, varscan2
- PLXNA3 | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.685); catalogued as rs1297686048, COSV63753014; called by muse, mutect2, varscan2
- PLXNB1 | c.4245G>T p.E1415D | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV56486316; called by muse, mutect2, varscan2
- PMFBP1 | c.670C>T p.R224W | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs747852400, COSV52820065; called by muse, mutect2, varscan2
- PNLDC1 | c.475C>T p.R159W | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs780297384, COSV51703526; called by muse, mutect2, varscan2
- PNPT1 | c.839C>T p.S280L | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs143022417, COSV53175373; called by muse, mutect2, varscan2
- PODN | c.908del p.P303Rfs*7 (on ENST00000395871; = p.P255Rfs*7 on NM_153703.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 44/260 reads (17%) | catalogued as rs1464111568, COSV57017199; called by mutect2, pindel, varscan2
- PODXL2 | c.1507G>A p.V503M | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs748147701, COSV51739825; called by muse, mutect2, varscan2
- POU3F4 | c.518G>A p.G173D | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV64537560; called by muse, mutect2, varscan2
- POU6F2 | c.419C>T p.T140I | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV68866899; called by muse, mutect2, varscan2
- PPM1N | c.1086del p.S363Afs*2 | Frame Shift Del (DEL) | VAF 5/20 reads (25%) | catalogued as rs1168946256; called by mutect2, varscan2
- PPP1R16A | c.577C>T p.R193C | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV52952095; called by muse, mutect2
- PPP2R2C | c.1174C>T p.R392C | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs763204097, COSV59441518; called by muse, mutect2, varscan2
- PPP6R1 | c.1951G>A p.A651T | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs769048528, COSV69799162; called by muse, mutect2, varscan2
- PPT2 | c.422G>A p.G141E | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1389953414, COSV52997399; called by muse, mutect2, varscan2
- PRDM14 | c.889G>A p.G297R | Missense Mutation (SNP) | VAF 44/155 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.049); catalogued as rs267601982, COSV52570372; called by muse, mutect2, varscan2
- PRDM15 | c.2417A>G p.H806R | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1396835094, COSV54148284; called by muse, mutect2, varscan2
- PREX1 | c.4862G>A p.R1621Q | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64247502; called by muse, mutect2, varscan2
- PRICKLE4 | c.844G>T p.G282W (on ENST00000359201; = p.G322W on NM_013397.6) | Missense Mutation (SNP) | VAF 44/147 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); catalogued as COSV59253256; called by muse, mutect2, varscan2
- PRKACG | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.124); catalogued as rs1167402842, COSV55240604; called by muse, varscan2
- PRKD1 | c.2135T>G p.V712G | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV59558284; called by muse, mutect2, varscan2
- PRKDC | c.5476A>G p.T1826A | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.659); catalogued as rs1011219960, COSV58041238; called by muse, mutect2, varscan2
- PRMT2 | c.489+2T>C p.X163_splice | Splice Site (SNP) | VAF 28/134 reads (21%) | catalogued as COSV52453844; called by muse, mutect2, varscan2
- PROCR | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 65/177 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as COSV53824983; called by muse, mutect2, varscan2
- PROP1 | c.629del p.P210Hfs*26 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | catalogued as rs761018422, CD064618; ClinVar: uncertain significance; called by mutect2, varscan2
- PRR11 | c.66del p.E23Kfs*9 | Frame Shift Del (DEL) | VAF 11/46 reads (24%) | catalogued as rs753236928; called by mutect2, varscan2
- PRSS35 | c.751T>C p.W251R | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs185512193, COSV63800032; called by muse, mutect2, varscan2
- PRSS54 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 48/158 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as rs149972398; called by muse, mutect2, varscan2
- PSMD11 | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.217); catalogued as COSV55577078; called by muse, mutect2, varscan2
- PTCHD1 | c.1462A>G p.K488E | Missense Mutation (SNP) | VAF 51/185 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.16); catalogued as COSV65058649; called by muse, mutect2, varscan2
- PTGER4 | c.389A>G p.Y130C | Missense Mutation (SNP) | VAF 71/249 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as COSV56719885; called by muse, mutect2, varscan2
- PTGIS | c.100C>A p.L34M | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.379); catalogued as COSV54834632; called by muse, mutect2, varscan2
- PTPN14 | c.1729A>G p.T577A | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.294); catalogued as COSV65281123; called by muse, mutect2, varscan2
- PTPRF | c.2383G>A p.V795I | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT tolerated (0.85); PolyPhen benign (0.009); catalogued as rs572629636, COSV63442134, COSV63447398; called by muse, mutect2, varscan2
- PTPRN2 | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs759890478, COSV67020053; called by muse, mutect2, varscan2
- PTPRU | c.3208G>A p.V1070M | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374116935; called by muse, mutect2, varscan2
- PXK | c.1568C>A p.P523Q | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as COSV57056226; called by muse, mutect2, varscan2
- QRICH2 | c.3784C>T p.R1262C | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); catalogued as rs974821346, COSV53150362; called by muse, mutect2, varscan2
- QSOX2 | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV62393243; called by muse, mutect2, varscan2
- RAB9B | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54587108; called by muse, mutect2, varscan2
- RALGAPB | c.2414G>A p.R805Q | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs558778710, COSV53434014; called by muse, mutect2, varscan2
- RALGPS2 | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV61335141; called by muse, mutect2, varscan2
- RANBP2 | c.3376C>T p.R1126W | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs370285906; ClinVar: likely benign; called by muse, mutect2, varscan2
- RAP1GAP | c.1498G>A p.A500T | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as rs376776052; called by muse, mutect2, varscan2
- RASA1 | c.1772G>A p.R591H | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as COSV57190784; called by muse, mutect2, varscan2
- RASIP1 | c.1174G>A p.A392T | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.127); catalogued as rs201455569, COSV55802117; called by muse, mutect2
- RBM5 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.953); catalogued as rs746587173, COSV61736371; called by muse, mutect2, varscan2
- RBPJL | c.1447C>T p.P483S | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV59212498; called by muse, varscan2
- RBPJL | c.1522C>T p.R508C | Missense Mutation (SNP) | VAF 41/209 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); catalogued as rs1258541761, COSV59212506; called by muse, varscan2
- RGS12 | c.2386C>T p.R796C | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as rs200267242, COSV58748343; called by muse, mutect2, varscan2
- RGS3 | c.618_620del p.F207del (on ENST00000350696 / NM_001282923.2; = p.F95del on NM_017790.4) | In Frame Del (DEL) | VAF 12/62 reads (19%) | catalogued as rs762481352; called by pindel, varscan2
- RNASE10 | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as rs1289253402, COSV60517339; called by muse, mutect2, varscan2
- RNF213 | c.2191C>T p.R731W | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757553323, COSV60621271; called by muse, mutect2, varscan2
- RNF217 | c.280G>A p.G94R | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.052); catalogued as rs762875854, COSV101451376, COSV101451399; called by muse, mutect2, varscan2
- RP1 | c.5125G>A p.V1709M | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.07); catalogued as rs747095891, COSV55109294; called by muse, mutect2, varscan2
- RPGR | c.2944G>T p.D982Y (on ENST00000339363 / NM_001367249.1; = p.D777Y on NM_000328.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV58839522; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 9/26 reads (35%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPRD2 | c.3685C>T p.R1229* | Nonsense Mutation (SNP) | VAF 7/111 reads (6%) | catalogued as COSV64818481; called by muse, mutect2
- RPS6KA3 | c.910A>G p.K304E | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.066); catalogued as COSV65386709; called by muse, mutect2, varscan2
- RRAGB | c.688C>A p.L230I (on ENST00000262850 / NM_016656.4; = p.L202I on NM_006064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV53328332; called by muse, mutect2, varscan2
- RREB1 | c.2819C>T p.P940L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58552721; called by muse, mutect2, varscan2
- RREB1 | c.3491G>A p.R1164H | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.226); catalogued as rs371044808; called by muse, varscan2
- RRNAD1 | c.1010G>A p.R337Q | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as rs564040904, COSV63928607; called by muse, mutect2, varscan2
- RSF1 | c.1158del p.K386Nfs*6 | Frame Shift Del (DEL) | VAF 19/78 reads (24%) | catalogued as rs1451848162, COSV100408029; called by mutect2, pindel, varscan2
- RTL5 | c.1511G>A p.S504N | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.027); catalogued as COSV65452243; called by muse, mutect2, varscan2
- RUSC1 | c.305G>C p.C102S | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.092); catalogued as COSV52737985; called by muse, mutect2, varscan2
- RXRA | c.485C>T p.T162M | Missense Mutation (SNP) | VAF 67/208 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62683390; called by muse, varscan2
- RYR2 | c.10040A>G p.D3347G | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.2); catalogued as rs1269582045, COSV63657588; called by muse, mutect2, varscan2
- SALL4 | c.2944G>A p.V982M | Missense Mutation (SNP) | VAF 49/131 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778170676, COSV53849553; called by muse, mutect2, varscan2
- SAMD4B | c.23G>A p.G8D | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as COSV58749953; called by muse, mutect2, varscan2
- SART3 | c.1120C>T p.R374* (on ENST00000228284; = p.R356* on NM_014706.4) | Nonsense Mutation (SNP) | VAF 29/75 reads (39%) | catalogued as COSV57205123, COSV99934455; called by muse, mutect2, varscan2
- SASH3 | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1439129682, COSV63555591; called by muse, mutect2, varscan2
- SBNO1 | c.419G>A p.R140Q (on ENST00000420886; = p.R139Q on NM_018183.5) | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.194); catalogued as rs1185327988, COSV57338500, COSV57344942; called by muse, mutect2, varscan2
- SCAF8 | c.3530G>A p.R1177H | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.869); catalogued as rs1056240217, COSV65789720; called by muse, mutect2, varscan2
- SCN10A | c.2276G>A p.R759H | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1048676042, COSV71860093, COSV71862925; called by muse, mutect2, varscan2
- SCN2A | c.5656T>C p.S1886P | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as COSV51830594; called by muse, mutect2, varscan2
- SCRIB | c.2573G>A p.R858H | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as rs782812033, COSV57581736; called by muse, mutect2
- SDK1 | c.3491G>T p.R1164L | Missense Mutation (SNP) | VAF 56/226 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67354851, COSV67370814; called by muse, mutect2, varscan2
- SDK2 | c.3550G>A p.G1184R | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1348129066, COSV66180609; called by muse, mutect2, varscan2
- SDK2 | c.3214C>T p.R1072C | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as rs1258292112, COSV66180615; called by muse, varscan2
- SECISBP2 | c.1880G>A p.R627H | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs149816537; called by muse, mutect2, varscan2
- SELENON | c.733C>T p.P245S | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.996); catalogued as COSV62523853; called by muse, mutect2, varscan2
- SEM1 | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 26/72 reads (36%) | catalogued as rs199922834; called by muse, mutect2, varscan2
- SEMA4D | c.1069C>T p.R357C | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as rs1436328465, COSV59390471; called by muse, mutect2, varscan2
- SEMA5B | c.2335T>C p.W779R | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52089504; called by muse, mutect2
- SEMA5B | c.2108G>A p.C703Y | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52089527; called by muse, varscan2
- SEPTIN1 | c.611G>T p.R204L (on ENST00000321367; = p.R157L on NM_052838.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV58441193; called by muse, mutect2, varscan2
- SEPTIN12 | c.19T>C p.S7P | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as COSV51615309; called by muse, mutect2
- SEPTIN14 | c.656G>A p.G219D | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs149607538; called by muse, mutect2, varscan2
- SEZ6 | c.531del p.S178Afs*121 | Frame Shift Del (DEL) | VAF 8/35 reads (23%) | catalogued as rs752308787, COSV57984595; called by mutect2, pindel, varscan2
- SFMBT2 | c.2111G>A p.R704Q | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs148221260, COSV100738728; called by muse, mutect2, varscan2
- SGO2 | c.1929del p.G644Vfs*18 | Frame Shift Del (DEL) | VAF 26/106 reads (25%) | catalogued as rs1260834379; called by pindel, varscan2
- SH3KBP1 | c.1822G>A p.A608T | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.104); catalogued as COSV65645979; called by muse, mutect2
- SHROOM3 | c.2171G>A p.R724Q | Missense Mutation (SNP) | VAF 49/137 reads (36%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.478); catalogued as COSV56022443; called by muse, mutect2, varscan2
- SIPA1L2 | c.3398G>A p.G1133D | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as COSV53382647; called by muse, mutect2, varscan2
- SIPA1L2 | c.3142G>A p.D1048N | Missense Mutation (SNP) | VAF 39/152 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.259); catalogued as rs192387110; called by muse, mutect2, varscan2
- SIPA1L2 | c.739G>A p.A247T | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.546); catalogued as rs1558236801, COSV53382682; called by muse, mutect2, varscan2
- SIRPB2 | c.11C>T p.T4M | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs372457994; called by muse, mutect2
- SLC12A6 | c.617del p.L206Yfs*28 (on ENST00000354181 / NM_001365088.1; = p.L155Yfs*28 on NM_005135.2) | Frame Shift Del (DEL) | VAF 18/58 reads (31%) | catalogued as rs916571899; called by mutect2, pindel, varscan2
- SLC12A9 | c.1711G>A p.D571N | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.044); catalogued as rs376415162, COSV51934748; called by mutect2, varscan2
- SLC1A6 | c.1229G>A p.R410H | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV55667543; called by muse, mutect2, varscan2
- SLC22A12 | c.1096G>A p.G366S | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1047976958, CM139309, COSV60570712; called by muse, mutect2, varscan2
729 further variants in this file (393 protein-altering or splice-affecting, 311 silent, 25 other) are not listed here.
